Somatic mutation profile of tumor specimen TCGA-D1-A2G0-01A (aliquot TCGA-D1-A2G0-01A-11D-A17D-09) from TCGA case TCGA-D1-A2G0, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 70.0 years (25,573 days).
Specimen TCGA-D1-A2G0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f087a719-6020-407f-b425-6da6326d8336.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A2G0-10A (Blood Derived Normal), aliquot TCGA-D1-A2G0-10A-01D-A17D-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4673eed5-81be-4242-aef5-ca37ef58f8b4

The open-access MAF lists 1,018 somatic variants for this specimen: 764 protein-altering or splice-affecting, 229 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 475, Silent 229, Frame Shift Del 192, Frame Shift Ins 37, Nonsense Mutation 31, In Frame Del 13, Intron 10, Splice Site 10, 3'UTR 5, Splice Region 4, 5'Flank 4, RNA 2.

Variants (750 of 1,018; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMHR2 | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374247138; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CCND1 | c.857C>T p.T286I | Missense Mutation (SNP) | VAF 17/29 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57119829, COSV99919330; called by muse, mutect2, varscan2
- COL1A1 | c.1127del p.P376Lfs*165 | Frame Shift Del (DEL) | VAF 25/80 reads (31%) | catalogued as rs72645369, CD961894; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CYP7B1 | c.1162C>T p.R388* | Nonsense Mutation (SNP) | VAF 32/61 reads (52%) | catalogued as rs72554620, CM982052, COSV59581636; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DNAH5 | c.13458dup p.N4487* | Frame Shift Ins (INS) | VAF 9/35 reads (26%) | catalogued as rs775696136; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ESCO2 | c.505C>T p.R169* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | catalogued as rs80359849, CM053853, COSV100533305; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1436G>A p.R479Q (on ENST00000281708 / NM_001349798.2; = p.R399Q on NM_018315.5) | Missense Mutation (SNP) | VAF 10/22 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs866987936, COSV55890822, COSV55894913, COSV55899054; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KDM5C | c.807del p.T270Qfs*2 | Frame Shift Del (DEL) | VAF 25/84 reads (30%) | catalogued as rs1569278313; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- MEN1 | c.1561del p.R521Gfs*43 | Frame Shift Del (DEL) | VAF 9/25 reads (36%) | catalogued as rs767319284, CD972318, CM080439, COSV53644931; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NPHS2 | c.467del p.L156Cfs*25 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | catalogued as rs528833893, CD042219; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- PKHD1 | c.3467C>T p.S1156L | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs367707903, CM051143, COSV100584356; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SLCO2A1 | c.830del p.F277Sfs*8 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | catalogued as rs751192029; ClinVar: pathogenic; called by mutect2, varscan2
- WRN | c.3382del p.S1128Vfs*34 | Frame Shift Del (DEL) | VAF 43/94 reads (46%) | catalogued as rs778872619; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AADACL3 | c.762del p.Q255Kfs*14 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | catalogued as rs746497630; called by mutect2, varscan2
- ABAT | c.479C>T p.T160I | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99190968; called by muse, mutect2, varscan2
- ABCA10 | c.4250C>T p.T1417M | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as rs185824716, COSV99288804; called by muse, mutect2, varscan2
- ABCA5 | c.742del p.I248* | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | catalogued as rs751460805, COSV67017665; called by mutect2, varscan2
- ABCA9 | c.1615+1G>A p.X539_splice | Splice Site (SNP) | VAF 14/78 reads (18%) | catalogued as rs768793413, COSV100383216, COSV60622389; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.463A>T p.M155L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious, low confidence (0.02); catalogued as COSV99865454; called by muse, mutect2, varscan2
- ACACB | c.4958A>G p.N1653S | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.852); catalogued as rs1387239626, COSV100623040; called by muse, mutect2, varscan2
- ACIN1 | c.2938C>T p.R980C | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99399814; called by muse, mutect2, varscan2
- ACOT2 | c.679G>C p.G227R | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV99469064; called by muse, mutect2, varscan2
- ACTRT2 | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); catalogued as rs757415381, COSV101007620; called by muse, mutect2, varscan2
- ACVR2A | c.285del p.D96Tfs*54 | Frame Shift Del (DEL) | VAF 16/36 reads (44%) | catalogued as rs1312707585, COSV54026507; called by mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 24/54 reads (44%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM22 | c.146G>A p.S49N | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV99717334; called by muse, mutect2, varscan2
- ADAMTS12 | c.2767C>T p.P923S | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV100711180; called by muse, mutect2, varscan2
- ADAMTS17 | c.1484G>A p.C495Y | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99170862; called by muse, mutect2, varscan2
- ADAP2 | c.1115C>T p.A372V | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs938504017, COSV100437277; called by muse, mutect2, varscan2
- ADARB2 | c.1908del p.F637Sfs*3 | Frame Shift Del (DEL) | VAF 33/95 reads (35%) | catalogued as COSV101184579; called by mutect2, pindel, varscan2
- ADCY5 | c.2164C>T p.R722C | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); catalogued as rs1412031145, COSV59194201; called by muse, mutect2
- ADGRB2 | c.1469C>T p.T490M | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1264381159, COSV99926478; called by muse, mutect2, varscan2
- ADGRG6 | c.3658C>T p.P1220S | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.001); catalogued as COSV99747647; called by muse, mutect2, varscan2
- ADH5 | c.328C>A p.L110I | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); catalogued as COSV56447977; called by muse, mutect2, varscan2
- ADRA2B | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.043); catalogued as COSV69787148; called by muse, mutect2
- ADRB2 | c.551G>A p.C184Y | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100019241; called by muse, mutect2, varscan2
- ADSS2 | c.59G>A p.R20H | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.339); catalogued as rs756788957, COSV100836868; called by muse, mutect2, varscan2
- AGAP1 | c.380G>C p.G127A | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs773218170, COSV58319853, COSV58340917; called by muse, mutect2, varscan2
- AHCTF1 | c.4151C>T p.T1384I (on ENST00000366508; = p.T1358I on NM_015446.5) | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs769420501, COSV100403934; called by muse, mutect2, varscan2
- AK9 | c.5168C>T p.A1723V | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.448); catalogued as rs753059975, COSV69850273; called by muse, mutect2, varscan2
- AKT1S1 | c.495del p.T166Pfs*87 (on ENST00000344175 / NM_001098633.4; = p.T186Pfs*87 on NM_032375.5) | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | catalogued as rs748776119, COSV59276444; called by mutect2, pindel, varscan2
- AKT1S1 | c.371A>G p.D124G (on ENST00000344175 / NM_001098633.4; = p.D144G on NM_032375.5) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as COSV99680750; called by muse, mutect2, varscan2
- AL645922.1 | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.216); catalogued as rs567227615, COSV54959236; called by muse, mutect2
- ALDH1A3 | c.849del p.K284Rfs*83 | Frame Shift Del (DEL) | VAF 12/51 reads (24%) | catalogued as rs758955164; called by mutect2, pindel, varscan2
- ALG13 | c.2173C>T p.P725S | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99322479; called by muse, mutect2, varscan2
- ALK | c.4390C>T p.R1464* | Nonsense Mutation (SNP) | VAF 10/70 reads (14%) | catalogued as rs374135358, COSV101201808; called by muse, mutect2, varscan2
- ANAPC7 | c.1586T>C p.M529T | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.105); catalogued as COSV101482866; called by muse, mutect2, varscan2
- ANK1 | c.3335C>A p.P1112H | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99225653; called by muse, mutect2, varscan2
- ANK3 | c.76del p.R26Gfs*21 | Frame Shift Del (DEL) | VAF 13/44 reads (30%) | catalogued as rs1373792937; called by mutect2, pindel, varscan2
- ANKIB1 | c.437del p.N146Tfs*12 | Frame Shift Del (DEL) | VAF 7/42 reads (17%) | catalogued as rs201434379; called by mutect2, varscan2
- ANKRD20A1 | c.1376del p.N459Ifs*5 | Frame Shift Del (DEL) | VAF 16/18 reads (89%) | catalogued as rs1296524808; called by mutect2, varscan2
- ANXA9 | c.952A>G p.K318E | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.05); catalogued as rs746823955, COSV100385463; called by muse, mutect2, varscan2
- AP4E1 | c.2663C>A p.P888H | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99956779; called by muse, mutect2, varscan2
- APIP | c.283del p.S95Afs*8 | Frame Shift Del (DEL) | VAF 22/71 reads (31%) | catalogued as rs546686089; called by mutect2, varscan2
- APOBEC3H | c.437A>G p.E146G | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.225); catalogued as rs1427946652, COSV100818847; called by muse, mutect2, varscan2
- AQP8 | c.194T>C p.L65P | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV99563993, COSV99564222; called by muse, mutect2, varscan2
- ARFGAP2 | c.276del p.R93Afs*43 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | catalogued as rs772728725, COSV54066450; called by mutect2, pindel, varscan2
- ARHGAP31 | c.1538C>T p.P513L | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.658); catalogued as rs886057800, COSV99957284; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGEF19 | c.590C>T p.S197L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99580557; called by muse, mutect2, varscan2
- ARID4A | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62162403; called by muse, mutect2, varscan2
- ARID4B | c.1629_1631del p.E553del | In Frame Del (DEL) | VAF 16/57 reads (28%) | catalogued as rs769873475; called by pindel, varscan2
- ARID5B | c.1658C>G p.S553* | Nonsense Mutation (SNP) | VAF 9/16 reads (56%) | catalogued as COSV99689901; called by muse, mutect2, varscan2
- ARMC8 | c.981G>A p.M327I (on ENST00000469044 / NM_001363941.2; = p.M313I on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.38); catalogued as COSV100627718; called by muse, mutect2, varscan2
- ARMCX3 | c.593G>T p.R198L | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.506); catalogued as COSV100362293; called by muse, mutect2
- ARNTL | c.935G>A p.S312N (on ENST00000403290 / NM_001297719.2; = p.S311N on NM_001178.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.075); catalogued as COSV100724764; called by muse, mutect2, varscan2
- ASB1 | c.518A>G p.N173S | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as rs80289904, COSV99223286; called by muse, mutect2, varscan2
- ATAD2 | c.4024A>T p.K1342* | Nonsense Mutation (SNP) | VAF 32/66 reads (48%) | catalogued as rs761794223, COSV54878294, COSV54881114; called by muse, mutect2, varscan2
- ATN1 | c.1918G>A p.G640R | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.174); catalogued as rs782212323, COSV100755838; called by muse, mutect2, varscan2
- ATP2B3 | c.2678C>T p.T893I | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV99684871; called by muse, mutect2, varscan2
- ATP6V0D2 | c.343G>A p.G115S | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53414655; called by muse, mutect2, varscan2
- ATP6V1B1 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs782603735, COSV52271364; called by muse, mutect2, varscan2
- ATP7B | c.4306G>A p.D1436N | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.887); catalogued as rs148081616, COSV99666580; called by muse, mutect2, varscan2
- BAHCC1 | c.6952G>A p.D2318N | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782736031, COSV100311763; called by muse, mutect2
- BARD1 | c.1788del p.K596Nfs*9 | Frame Shift Del (DEL) | VAF 12/39 reads (31%) | catalogued as COSV53612208; called by mutect2, pindel, varscan2
- BDP1 | c.3746A>G p.E1249G | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as rs376282264, COSV100703247; called by muse, mutect2, varscan2
- BEND5 | c.1052del p.K351Rfs*15 | Frame Shift Del (DEL) | VAF 22/69 reads (32%) | catalogued as rs756345162, COSV65718189; called by mutect2, varscan2
- BEST1 | c.838C>T p.Q280* | Nonsense Mutation (SNP) | VAF 28/68 reads (41%) | catalogued as COSV100077230; called by muse, mutect2, varscan2
- BEST2 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.053); catalogued as rs780198148, COSV50378398; called by muse, mutect2, varscan2
- BEST3 | c.1332del p.R445Gfs*40 | Frame Shift Del (DEL) | VAF 27/67 reads (40%) | catalogued as rs779566914, COSV58300788; called by mutect2, varscan2
- BICRA | c.2935del p.A979Pfs*67 | Frame Shift Del (DEL) | VAF 20/40 reads (50%) | catalogued as rs756990560, COSV67605323; called by mutect2, pindel, varscan2
- BIVM-ERCC5 | c.170G>A p.C57Y | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99958837; called by muse, mutect2, varscan2
- BLNK | c.209G>A p.S70N | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.195); catalogued as COSV99813981; called by muse, mutect2, varscan2
- BMP10 | c.1240G>T p.E414* | Nonsense Mutation (SNP) | VAF 25/73 reads (34%) | catalogued as COSV54894238, COSV99770474; called by muse, mutect2, varscan2
- BMP10 | c.524G>T p.G175V | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as COSV99770476; called by muse, mutect2, varscan2
- BMP10 | c.38G>A p.C13Y | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV99770478; called by muse, mutect2, varscan2
- BMP3 | c.651A>G p.I217M | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV99261791; called by muse, mutect2, varscan2
- BMPR1B | c.76del p.R26Vfs*31 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | catalogued as COSV99215447; called by mutect2, pindel, varscan2
- BRD3 | c.71del p.P24Rfs*24 | Frame Shift Del (DEL) | VAF 20/46 reads (43%) | catalogued as rs763134487; called by mutect2, varscan2
- BRPF3 | c.1235G>T p.G412V | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.169); catalogued as COSV100325945; called by muse, mutect2, varscan2
- C11orf24 | c.1229T>C p.V410A | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100422609; called by muse, mutect2, varscan2
- C12orf40 | c.793T>C p.S265P | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100210250, COSV100210375; called by muse, mutect2, varscan2
- C12orf42 | c.1009del p.R337Afs*19 | Frame Shift Del (DEL) | VAF 10/65 reads (15%) | catalogued as rs771322722; called by mutect2, pindel, varscan2
- C22orf31 | c.463A>T p.T155S | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.475); catalogued as COSV99326410; called by muse, mutect2, varscan2
- C3 | c.3365C>T p.A1122V | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV55573977; called by muse, mutect2, varscan2
- C3orf52 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99332499; called by muse, mutect2, varscan2
- C4BPA | c.1762G>A p.A588T | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.129); catalogued as rs369244342; called by muse, mutect2, varscan2
- C5orf38 | c.163G>A p.G55R | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.143); catalogued as rs769993024, COSV100121762, COSV100121830; called by muse, mutect2, varscan2
- C6orf89 | c.877C>T p.Q293* (on ENST00000373685; = p.Q300* on NM_152734.4) | Nonsense Mutation (SNP) | VAF 19/84 reads (23%) | catalogued as COSV62103358; called by muse, mutect2, varscan2
- CACNA1E | c.5702G>A p.R1901H | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as rs747480727, COSV100701293; called by muse, mutect2, varscan2
- CACNA1F | c.1496+1G>A p.X499_splice | Splice Site (SNP) | VAF 17/57 reads (30%) | catalogued as CS139723, COSV100545014; called by muse, mutect2, varscan2
- CACNA2D3 | c.2634del p.F878Lfs*8 | Frame Shift Del (DEL) | VAF 16/47 reads (34%) | catalogued as rs912442024; called by mutect2, pindel, varscan2
- CAMSAP2 | c.4309del p.M1437* (on ENST00000236925 / NM_001297707.2; = p.M1426* on NM_203459.3) | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | catalogued as rs1375954479; called by mutect2, pindel, varscan2
- CAPN15 | c.2734C>T p.Q912* | Nonsense Mutation (SNP) | VAF 16/61 reads (26%) | catalogued as COSV99562547; called by muse, mutect2, varscan2
- CAPZA3 | c.166T>G p.C56G | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.766); catalogued as COSV99856520; called by muse, mutect2, varscan2
- CARD10 | c.1578del p.S527Vfs*31 | Frame Shift Del (DEL) | VAF 20/65 reads (31%) | catalogued as rs35832225; called by mutect2, pindel, varscan2
- CARD8 | c.340dup p.D114Gfs*34 (on ENST00000651546 / NM_001184900.3; = p.D64Gfs*34 on NM_014959.5 and 3 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 26/34 reads (76%) | catalogued as rs770149864; called by mutect2, varscan2
- CASP5 | c.533del p.N178Ifs*8 | Frame Shift Del (DEL) | VAF 15/52 reads (29%) | catalogued as rs765105588; called by mutect2, varscan2
- CC2D2A | c.2978C>T p.A993V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV101052804; called by mutect2, varscan2
- CCDC124 | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV71490318; called by muse, mutect2, varscan2
- CCDC18 | c.774del p.V259Wfs*15 | Frame Shift Del (DEL) | VAF 20/44 reads (45%) | catalogued as rs746565576, COSV58142470; called by mutect2, varscan2
- CCDC39 | c.2515G>C p.D839H | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as rs1022857891, COSV99869510; called by muse, mutect2, varscan2
- CCN4 | c.419G>A p.C140Y | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.961); catalogued as COSV99137173; called by muse, mutect2, varscan2
- CCNF | c.1363G>A p.A455T | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs753790591, COSV53540569; called by muse, mutect2
- CDC42BPB | c.3798G>T p.E1266D | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0.04); catalogued as COSV100775486; called by muse, mutect2, varscan2
- CDC7 | c.572A>G p.K191R | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.173); catalogued as COSV52309844, COSV99319800; called by muse, mutect2, varscan2
- CDCA7 | c.431G>A p.R144H (on ENST00000347703 / NM_145810.3; = p.R223H on NM_031942.5) | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as rs774858532, COSV100143577; called by muse, mutect2, varscan2
- CDH3 | c.1915G>A p.D639N | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.14); catalogued as rs560120147, COSV99868623; called by muse, mutect2, varscan2
- CDH8 | c.1157A>T p.D386V | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100182349, COSV100182594; called by muse, mutect2
- CDK17 | c.883T>C p.Y295H | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as COSV54130725, COSV99702821; called by muse, mutect2, varscan2
- CDK18 | c.401G>A p.R134H (on ENST00000506784 / NM_212503.3; = p.R104H on NM_002596.4) | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.233); catalogued as rs759474576, COSV100774048; called by muse, mutect2, varscan2
- CDK9 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as COSV100953675; called by muse, mutect2, varscan2
- CDKL5 | c.1588C>G p.P530A | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.359); catalogued as COSV101184379; called by muse, mutect2, varscan2
- CEACAM5 | c.2068G>A p.G690S | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.065); catalogued as rs368131026; called by muse, mutect2
- CELSR1 | c.5389A>C p.T1797P | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); catalogued as COSV99418762; called by muse, mutect2, varscan2
- CELSR3 | c.9862C>T p.P3288S | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.884); catalogued as rs1389987031, COSV99373897; called by muse, mutect2, varscan2
- CELSR3 | c.8239C>A p.H2747N | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0.006); catalogued as COSV99373316; called by muse, mutect2, varscan2
- CEP290 | c.3214C>T p.R1072W | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780870106, COSV58350838; called by muse, mutect2, varscan2
- CEP70 | c.1747G>T p.D583Y | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53874281, COSV99389312; called by muse, mutect2, varscan2
- CFAP46 | c.6778C>T p.R2260C | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.458); catalogued as rs562594842, COSV99584221; called by muse, mutect2, varscan2
- CFP | c.146del p.G49Vfs*43 | Frame Shift Del (DEL) | VAF 7/26 reads (27%) | catalogued as rs749541242; called by mutect2, pindel, varscan2
- CGNL1 | c.1100A>G p.Q367R | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as rs774178105, COSV99848490; called by muse, mutect2, varscan2
- CHD1 | c.5122C>T p.R1708W | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs200109773; called by muse, mutect2, varscan2
- CHD3 | c.5917_5919del p.E1973del (on ENST00000330494 / NM_001005273.3; = p.E1939del on NM_005852.4) | In Frame Del (DEL) | VAF 14/38 reads (37%) | catalogued as rs1329089782; called by mutect2, pindel, varscan2
- CHD8 | c.1679C>T p.A560V (on ENST00000646647 / NM_001170629.2; = p.A281V on NM_020920.4) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as rs769523871, COSV67872454; called by muse, mutect2
- CHERP | c.1362del p.W455Gfs*200 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | catalogued as rs770045437; called by mutect2, pindel, varscan2
- CHRNB4 | c.1120G>T p.A374S | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.8); PolyPhen benign (0.014); catalogued as rs199844639, COSV99929417; called by muse, mutect2, varscan2
- CHST2 | c.1132G>A p.A378T | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0.044); catalogued as COSV58886070; called by muse, mutect2, varscan2
- CIDEA | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100255157; called by mutect2, varscan2
- CILP2 | c.1012C>T p.H338Y | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758993213, COSV99364839; called by muse, mutect2, varscan2
- CIT | c.3832G>A p.A1278T | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); catalogued as COSV99950037; called by muse, mutect2, varscan2
- CLASP2 | c.2896del p.M966Wfs*33 (on ENST00000359576; = p.M965Wfs*33 on NM_015097.3 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 16/46 reads (35%) | catalogued as rs761731080; called by mutect2, varscan2
- CLCF1 | c.50C>T p.T17M | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as rs1202119816, COSV100425658; called by muse, mutect2, varscan2
- CLCN6 | c.913T>G p.S305A | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV100412007; called by muse, mutect2, varscan2
- CLEC4A | c.284del p.N95Ifs*49 | Frame Shift Del (DEL) | VAF 20/49 reads (41%) | catalogued as rs760557093; called by mutect2, varscan2
- CLSTN1 | c.2327G>A p.R776H (on ENST00000377298 / NM_001009566.3; = p.R766H on NM_014944.4) | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs1405921597, COSV63646677, COSV63648317; called by muse, mutect2, varscan2
- CLSTN1 | c.1258C>A p.L420I (on ENST00000377298 / NM_001009566.3; = p.L410I on NM_014944.4) | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.951); catalogued as COSV100790632; called by muse, mutect2, varscan2
- CLSTN3 | c.2863C>A p.R955S | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.048); catalogued as COSV99867185; called by muse, mutect2, varscan2
- CLTCL1 | c.3839C>T p.A1280V | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.947); catalogued as COSV99595286; called by muse, mutect2, varscan2
- CNFN | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV99706197; called by muse, mutect2
- CNGB1 | c.1373-1G>A p.X458_splice | Splice Site (SNP) | VAF 20/59 reads (34%) | catalogued as COSV99203302; called by muse, mutect2, varscan2
- CNTN6 | c.1253del p.K418Sfs*63 | Frame Shift Del (DEL) | VAF 14/45 reads (31%) | catalogued as rs758676375; called by mutect2, varscan2
- CNTROB | c.2699dup p.V901Sfs*25 | Frame Shift Ins (INS) | VAF 12/41 reads (29%) | catalogued as rs35508310; called by mutect2, varscan2
- COL11A2 | c.5170C>T p.R1724W (on ENST00000341947 / NM_080680.3; = p.R1617W on NM_080679.2) | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs762351406, COSV59493447; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL12A1 | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.55); PolyPhen benign (0.063); catalogued as COSV100486165; called by muse, mutect2, varscan2
- COL22A1 | c.22G>C p.A8P | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV100278967; called by muse, mutect2, varscan2
- COL6A2 | c.1531G>A p.G511S | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs727502833, COSV100153766; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COMP | c.1172C>A p.P391H | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.944); catalogued as COSV99721481; called by muse, mutect2
- COQ9 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.887); catalogued as COSV99345847; called by muse, mutect2, varscan2
- CP | c.2209G>A p.A737T | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as rs758399451, COSV52831503; called by muse, mutect2, varscan2
- CPNE5 | c.1610T>C p.L537P | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV99782909; called by muse, mutect2, varscan2
- CPSF4 | c.806A>G p.Q269R | Missense Mutation (SNP) | VAF 52/107 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.304); catalogued as COSV99461780; called by muse, mutect2, varscan2
- CR2 | c.624del p.T209Hfs*10 | Frame Shift Del (DEL) | VAF 61/109 reads (56%) | catalogued as rs747832403; called by mutect2, pindel, varscan2
- CRABP2 | c.13T>C p.S5P | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as COSV100957563; called by muse, mutect2, varscan2
- CRACD | c.559G>A p.G187S | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV99073089, COSV99949491; called by muse, mutect2, varscan2
- CRBN | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs774818392, COSV99214225; called by muse, mutect2, varscan2
- CRELD1 | c.94T>C p.S32P | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV99925851; called by muse, mutect2, varscan2
- CSF2RA | c.131C>T p.T44M | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as rs746211899, COSV62624209; called by muse, mutect2, varscan2
- CSMD1 | c.5744C>T p.A1915V (on ENST00000520002; = p.A1914V on NM_033225.6) | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs751280237, COSV100149691; called by muse, mutect2, varscan2
- CSMD1 | c.1171C>T p.Q391* (on ENST00000520002; = p.Q390* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 16/53 reads (30%) | catalogued as COSV101221716; called by muse, mutect2, varscan2
- CSRNP2 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.784); catalogued as COSV57335146, COSV99950412; called by muse, mutect2, varscan2
- CTSA | c.990del p.C331Afs*36 | Frame Shift Del (DEL) | VAF 33/76 reads (43%) | catalogued as rs758642867; called by mutect2, pindel, varscan2
- CUL7 | c.1717C>A p.L573I | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.067); catalogued as COSV99538803; called by muse, mutect2, varscan2
- CXorf21 | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0.023); catalogued as rs369573227, COSV100973298; called by muse, mutect2, varscan2
- CYP24A1 | c.285G>T p.K95N | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as COSV99398392; called by muse, mutect2, varscan2
- DBR1 | c.1174G>A p.V392M | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.051); catalogued as COSV99604549; called by muse, mutect2, varscan2
- DCAF4 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs373000336; called by muse, mutect2, varscan2
- DCHS1 | c.3662del p.G1221Afs*16 | Frame Shift Del (DEL) | VAF 17/47 reads (36%) | catalogued as COSV55036069; called by mutect2, pindel, varscan2
- DDX20 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.041); catalogued as rs531878468, COSV100865942; called by muse, mutect2, varscan2
- DDX42 | c.2174C>T p.A725V | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as rs767638323, COSV100834964; called by muse, mutect2, varscan2
- DESI2 | c.263T>A p.I88N | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99798257; called by muse, mutect2, varscan2
- DHX38 | c.2241G>A p.M747I | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767652246, COSV99194359; called by muse, mutect2, varscan2
- DIP2B | c.223T>C p.S75P | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV99998755; called by muse, mutect2, varscan2
- DIS3L | c.329C>T p.A110V (on ENST00000319212 / NM_001143688.3; = p.A27V on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as rs866712900, COSV100055345; called by muse, mutect2, varscan2
- DLC1 | c.1849del p.R617Gfs*37 (on ENST00000276297 / NM_001348081.2; = p.R180Gfs*37 on NM_006094.5) | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | catalogued as COSV52307798; called by mutect2, pindel, varscan2
- DMD | c.1058C>T p.S353L | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as rs374713915, COSV55891649; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH10 | c.5878_5880del p.S1960del (on ENST00000409039; = p.S1899del on NM_207437.3) | In Frame Del (DEL) | VAF 5/32 reads (16%) | catalogued as rs981734772; called by pindel, varscan2
- DNAH9 | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.96); catalogued as rs373491778; called by muse, mutect2, varscan2
- DNAJC13 | c.1852A>G p.M618V | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV99607517; called by muse, mutect2, varscan2
- DNMT3L | c.323G>A p.C108Y | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99533335; called by muse, mutect2, varscan2
- DOCK6 | c.2627C>T p.A876V | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs764914767, COSV99625869; called by muse, mutect2, varscan2
- DOCK8 | c.3339del p.F1113Lfs*2 | Frame Shift Del (DEL) | VAF 24/69 reads (35%) | catalogued as rs748134881; called by mutect2, varscan2
- DOP1B | c.4532A>G p.Y1511C | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.086); catalogued as COSV101215527; called by muse, mutect2, varscan2
- DPYSL5 | c.515G>T p.S172I | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.597); catalogued as COSV99982495; called by muse, mutect2, varscan2
- DTX4 | c.1527del p.G510Afs*35 | Frame Shift Del (DEL) | VAF 13/46 reads (28%) | catalogued as rs762133243; called by mutect2, pindel, varscan2
- DUSP10 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.015); catalogued as COSV100100616; called by muse, mutect2, varscan2
- EDA | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.211); catalogued as COSV101000037; called by muse, mutect2, varscan2
- EFCAB7 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as rs575563288, COSV100391323; called by muse, mutect2, varscan2
- EIF4G2 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV101150928; called by muse, mutect2, varscan2
- ELK3 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV99957682; called by muse, mutect2, varscan2
- ELMO3 | c.26G>A p.R9H | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as rs1200827507, COSV100681743; called by muse, mutect2, varscan2
- ELP6 | c.410C>T p.T137M | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.56); catalogued as rs753825070, COSV99948176; called by muse, mutect2, varscan2
- EOGT | c.727+2T>C p.X243_splice | Splice Site (SNP) | VAF 14/36 reads (39%) | catalogued as COSV99808946; called by muse, mutect2, varscan2
- EPHA1 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs74721927, COSV51971522; called by muse, mutect2, varscan2
- EPHA2 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754639981, COSV64452591; called by muse, mutect2, varscan2
- EPHA6 | c.2743A>G p.R915G (on ENST00000389672 / NM_001080448.3; = p.R307G on NM_173655.4) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101063690; called by muse, mutect2, varscan2
- EPRS1 | c.1042A>G p.N348D | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs764796744, COSV100859411; called by muse, mutect2, varscan2
- ERN1 | c.2180G>A p.R727H | Missense Mutation (SNP) | VAF 68/95 reads (72%) | SIFT deleterious (0.04); PolyPhen benign (0.283); catalogued as rs769854043, COSV101458404, COSV101458419; called by muse, mutect2, varscan2
- ESPNL | c.1019C>T p.P340L | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.133); catalogued as rs752883260, COSV100547848; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 22/82 reads (27%) | catalogued as rs775950025; called by mutect2, varscan2
- ETV4 | c.550G>A p.V184I | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as rs746055784, COSV100081757, COSV60044513; called by muse, mutect2, varscan2
- EVI5L | c.2128C>T p.P710S | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.6); PolyPhen benign (0.079); catalogued as COSV99563278; called by muse, mutect2
- FAAH2 | c.233T>C p.I78T | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1160543178, COSV100887358; called by muse, mutect2, varscan2
- FAM120A | c.2277T>C p.I759= | Splice Region (SNP) | VAF 11/43 reads (26%) | catalogued as COSV99465853; called by muse, mutect2, varscan2
- FAM13B | c.1849C>T p.R617W | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs375616241; called by muse, mutect2, varscan2
- FAM151B | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as rs146970475; called by muse, mutect2, varscan2
- FAM171B | c.1954G>A p.G652R | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); catalogued as COSV100488711; called by muse, mutect2, varscan2
- FAM177B | c.118G>T p.E40* | Nonsense Mutation (SNP) | VAF 7/19 reads (37%) | catalogued as COSV100680404; called by muse, mutect2, varscan2
- FAM47C | c.1787del p.P596Rfs*229 | Frame Shift Del (DEL) | VAF 17/114 reads (15%) | catalogued as COSV63724780; called by mutect2, pindel, varscan2
- FAM91A1 | c.2213G>A p.R738Q | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs773531913, COSV100593646; called by muse, mutect2, varscan2
- FAM9A | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.682); catalogued as COSV101121354; called by muse, mutect2, varscan2
- FARP2 | c.2081G>A p.R694H | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs533193274, COSV99884850; called by muse, mutect2, varscan2
- FASN | c.3125C>T p.A1042V | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1472997889, COSV100147953; called by muse, mutect2, varscan2
- FAT1 | c.5630dup p.V1878Cfs*8 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | catalogued as rs1560943587; called by pindel, varscan2
- FAT1 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765758588, COSV71673258; called by muse, mutect2, varscan2
- FBF1 | c.2066A>G p.Q689R (on ENST00000586717; = p.Q703R on NM_001319193.1) | Missense Mutation (SNP) | VAF 58/115 reads (50%) | SIFT tolerated (0.64); PolyPhen benign (0.395); catalogued as rs1474097477, COSV100045287; called by muse, mutect2, varscan2
- FBLN5 | c.934T>C p.F312L | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV99969694; called by muse, mutect2
- FBN1 | c.2092C>T p.P698S | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs1085307625, COSV57314856; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FCRLA | c.435del p.P147Lfs*65 (on ENST00000367959; = p.P124Lfs*65 on NM_032738.4) | Frame Shift Del (DEL) | VAF 4/27 reads (15%) | catalogued as COSV52685605; called by mutect2, pindel, varscan2
- FFAR3 | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT tolerated (0.9); PolyPhen benign (0.007); catalogued as rs376071323; called by muse, mutect2, varscan2
- FGD6 | c.3396G>A p.M1132I | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated (0.05); PolyPhen benign (0.057); catalogued as COSV100676655; called by muse, mutect2, varscan2
- FHOD3 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs1447047402, COSV99941586; called by muse, mutect2, varscan2
- FHOD3 | c.2683C>T p.R895C (on ENST00000359247 / NM_001281739.3; = p.R912C on NM_025135.5) | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761939836, COSV57171133; called by muse, mutect2, varscan2
- FIBCD1 | c.1207G>A p.A403T | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as rs1019642247, COSV53394663; called by muse, mutect2, varscan2
- FIBIN | c.128A>G p.Y43C | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100590471; called by muse, mutect2, varscan2
- FIBP | c.688G>A p.D230N (on ENST00000338369 / NM_198897.2; = p.D223N on NM_004214.5) | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); catalogued as rs761285384, COSV100327414; called by muse, mutect2, varscan2
- FLT1 | c.2952G>T p.E984D | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.075); catalogued as COSV56725347; called by muse, mutect2, varscan2
- FMO4 | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100882075; called by muse, mutect2, varscan2
- FN1 | c.548-1G>A p.X183_splice | Splice Site (SNP) | VAF 9/38 reads (24%) | catalogued as COSV100117372; called by muse, mutect2
- FNDC1 | c.4579A>C p.I1527L | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (0.46); PolyPhen benign (0.097); catalogued as COSV99796101; called by muse, mutect2, varscan2
- FOXC2 | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.023); catalogued as rs1190156347, COSV100234306; called by muse, mutect2, varscan2
- FOXI2 | c.926T>A p.L309H | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV100511027; called by muse, mutect2, varscan2
- FOXP4 | c.1576G>A p.V526I (on ENST00000307972 / NM_001012426.1; = p.V513I on NM_138457.3) | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); catalogued as rs772487810, COSV100332807; called by muse, mutect2, varscan2
- FRMD7 | c.797C>A p.A266D | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100049091; called by muse, mutect2, varscan2
- FRMPD1 | c.2045C>G p.T682R | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV100899583; called by muse, mutect2, varscan2
- FRMPD4 | c.3326C>T p.A1109V | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.005); catalogued as COSV101043229; called by muse, mutect2, varscan2
- FRZB | c.112G>A p.V38I | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.125); catalogued as COSV54554805; called by muse, mutect2, varscan2
- FTCD | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as rs371619712; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GABRA2 | c.1141G>A p.D381N | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.034); catalogued as COSV100734433, COSV62915090; called by muse, mutect2, varscan2
- GABRA2 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV100734434; called by muse, mutect2
- GABRP | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.419); catalogued as COSV99516877; called by muse, mutect2, varscan2
- GADD45A | c.448A>G p.S150G | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV100921465; called by muse, mutect2, varscan2
- GAN | c.490G>A p.V164I | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.816); catalogued as rs778744880, COSV101634006; called by muse, mutect2, varscan2
- GAP43 | c.11G>A p.C4Y | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV100525684; called by muse, mutect2, varscan2
- GBP5 | c.926G>A p.C309Y | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100600121; called by muse, mutect2, varscan2
- GIPC3 | c.374C>A p.T125N | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100461360; called by muse, mutect2, varscan2
- GMIP | c.1749G>T p.Q583H | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99179339; called by muse, mutect2
- GNAZ | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs760505008, COSV99320905; called by muse, mutect2, varscan2
- GNB5 | c.226C>T p.H76Y (on ENST00000261837 / NM_016194.4; = p.H34Y on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV99953440; called by muse, mutect2, varscan2
- GNG12 | c.202del p.T68Lfs*22 | Frame Shift Del (DEL) | VAF 25/72 reads (35%) | catalogued as rs1022402829; called by mutect2, pindel, varscan2
- GNL3L | c.1150G>A p.A384T | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV100328464; called by muse, mutect2
- GOLGA6L9 | c.562C>A p.Q188K | Missense Mutation (SNP) | VAF 61/228 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.146); catalogued as rs1235594402; called by muse, mutect2, varscan2
- GPR149 | c.2170A>G p.R724G | Missense Mutation (SNP) | VAF 50/82 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as rs1224240049, COSV101078528; called by muse, mutect2, varscan2
- GPR171 | c.740C>G p.T247S | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56398264, COSV99853637; called by muse, mutect2, varscan2
- GPR173 | c.661C>T p.Q221* | Nonsense Mutation (SNP) | VAF 14/37 reads (38%) | catalogued as COSV100212311; called by muse, mutect2, varscan2
- GPR20 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 49/91 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs148158345; called by muse, mutect2, varscan2
- GPT2 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.758); catalogued as rs1045338829, COSV60840389; called by muse, mutect2, varscan2
- GRAMD1B | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1179255945, COSV100454863; called by muse, mutect2, varscan2
- GRK2 | c.1541C>T p.S514L | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs765668445, COSV100419529; called by muse, mutect2, varscan2
- GRM7 | c.1025C>T p.T342M | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as rs755371859, COSV100736531; called by muse, mutect2, varscan2
- GSR | c.560G>A p.S187N | Missense Mutation (SNP) | VAF 78/145 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55320458, COSV55322856; called by muse, mutect2, varscan2
- GSX1 | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as COSV100262578; called by muse, mutect2, varscan2
- GSX2 | c.271G>A p.G91R | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs779734371, COSV58842770; called by muse, varscan2
- GTF2IRD2 | c.1696T>G p.F566V | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100736442; called by muse, mutect2, varscan2
- GYS2 | c.1327G>A p.V443M | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99679879; called by muse, mutect2, varscan2
- H3-3B | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.047); catalogued as COSV99638077; called by muse, mutect2, varscan2
- HCFC1R1 | c.109G>T p.G37* | Nonsense Mutation (SNP) | VAF 17/39 reads (44%) | catalogued as COSV50187795, COSV99560668; called by muse, mutect2, varscan2
- HECTD4 | c.10345G>A p.G3449R | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs537066715, COSV101107828; called by muse, mutect2, varscan2
- HELLS | c.1840del p.R614Efs*11 | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | catalogued as rs745837238; called by mutect2, varscan2
- HELQ | c.2873A>G p.N958S | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.416); catalogued as COSV99787850; called by muse, mutect2, varscan2
- HELZ2 | c.7762G>A p.V2588I (on ENST00000467148 / NM_001037335.2; = p.V2019I on NM_033405.3) | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.547); catalogued as rs201718588, COSV100918807; called by muse, mutect2, varscan2
- HERC6 | c.1732C>T p.R578* | Nonsense Mutation (SNP) | VAF 22/56 reads (39%) | catalogued as rs1167613600, COSV99986761; called by muse, mutect2, varscan2
- HES1 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.222); catalogued as rs1270230843, COSV51684577; called by muse, mutect2, varscan2
- HEXD | c.1397G>A p.S466N (on ENST00000327949 / NM_001369487.1; = p.A496T on NM_173620.3) | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV100027791; called by muse, mutect2, varscan2
- HGFAC | c.1432G>A p.G478S | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as rs757247328, COSV101237765; called by muse, mutect2, varscan2
- HLA-G | c.627del p.K210Rfs*4 | Frame Shift Del (DEL) | VAF 33/142 reads (23%) | catalogued as rs752829354, COSV64406835; called by mutect2, pindel, varscan2
- HMCN1 | c.14930G>A p.G4977D | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754167094, COSV99630875; called by muse, mutect2, varscan2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 8/16 reads (50%) | catalogued as rs761272507; called by mutect2, varscan2
- HNRNPH1 | c.61T>C p.S21P | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100270741; called by muse, mutect2, varscan2
- HNRNPM | c.1924G>A p.G642R | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV99725649; called by muse, mutect2, varscan2
- HOXC6 | c.626dup p.G210Rfs*63 | Frame Shift Ins (INS) | VAF 12/57 reads (21%) | catalogued as rs765056816; called by mutect2, pindel, varscan2
- IFNAR2 | c.145C>T p.R49W | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs375487848; called by muse, mutect2, varscan2
- IGF2R | c.3949dup p.D1317Gfs*5 | Frame Shift Ins (INS) | VAF 13/38 reads (34%) | catalogued as rs760021495; called by mutect2, varscan2
- IK | c.1139G>T p.R380I | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.55); catalogued as COSV101341794; called by muse, mutect2, varscan2
- IKZF1 | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.825); catalogued as rs1410124404, COSV58784894; called by muse, mutect2, varscan2
- IL1RAPL2 | c.157T>C p.C53R | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100781469; called by muse, mutect2, varscan2
- IL1RL2 | c.835C>T p.R279* | Nonsense Mutation (SNP) | VAF 16/43 reads (37%) | catalogued as rs774693759, COSV51819856; called by muse, mutect2, varscan2
- IL21R | c.1549dup p.R517Pfs*48 | Frame Shift Ins (INS) | VAF 14/40 reads (35%) | catalogued as rs748992699; called by mutect2, varscan2
- ING1 | c.1169C>A p.P390H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58168791; called by muse, mutect2, varscan2
- INPP5K | c.1291-1G>A p.X431_splice | Splice Site (SNP) | VAF 9/27 reads (33%) | catalogued as COSV100233799; called by muse, mutect2, varscan2
- IP6K3 | c.913C>T p.Q305* | Nonsense Mutation (SNP) | VAF 15/48 reads (31%) | catalogued as COSV99539915; called by muse, mutect2, varscan2
- IQCA1 | c.1852C>A p.L618M | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.369); catalogued as COSV99609789; called by muse, mutect2, varscan2
- IQCH | c.2894T>C p.M965T | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs569975447, COSV100245982; called by muse, mutect2, varscan2
- IQSEC2 | c.2614G>A p.V872M (on ENST00000642864 / NM_001111125.3; = p.V667M on NM_015075.2) | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100944962; called by muse, mutect2, varscan2
- IRGQ | c.61T>C p.S21P | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100338185; called by muse, mutect2
- IRS1 | c.1791dup p.H598Afs*13 | Frame Shift Ins (INS) | VAF 34/96 reads (35%) | catalogued as rs761880048; called by mutect2, varscan2
- ITGA6 | c.3351del p.K1117Nfs*? (on ENST00000442250; = p.K1078Nfs*48 on NM_001079818.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 10/18 reads (56%) | catalogued as rs201055917; ClinVar: uncertain significance; called by mutect2, varscan2
- ITIH5 | c.2597C>A p.P866H | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.029); catalogued as COSV99904963; called by muse, mutect2, varscan2
- ITIH6 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.613); catalogued as rs527740087, COSV99513462; called by muse, mutect2, varscan2
- JAK3 | c.115del p.Q39Sfs*108 | Frame Shift Del (DEL) | VAF 22/54 reads (41%) | catalogued as rs755706305; called by mutect2, pindel, varscan2
- JHY | c.506C>T p.T169M | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); catalogued as rs564515467, COSV99913349; called by muse, mutect2, varscan2
- JMJD1C | c.1112A>G p.N371S | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.374); catalogued as rs528244230, COSV67863018; ClinVar: likely benign; called by muse, mutect2, varscan2
- JRK | c.245A>G p.H82R | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.991); catalogued as COSV101401111; called by muse, mutect2
- KALRN | c.8681G>T p.R2894M (on ENST00000360013 / NM_001024660.4; = p.R1197M on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV52259727, COSV52260509; called by muse, mutect2, varscan2
- KAT6A | c.4651A>C p.S1551R | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55911622, COSV99705346; called by muse, mutect2, varscan2
- KBTBD6 | c.1326dup p.R443Afs*8 | Frame Shift Ins (INS) | VAF 22/56 reads (39%) | catalogued as rs774820321; called by mutect2, varscan2
- KCMF1 | c.52C>T p.R18* | Nonsense Mutation (SNP) | VAF 14/31 reads (45%) | catalogued as COSV69053190, COSV69053501; called by muse, mutect2, varscan2
- KCNA1 | c.1180A>G p.I394V | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.407); catalogued as COSV101230292; called by muse, mutect2, varscan2
- KCNAB1 | c.956T>C p.L319P (on ENST00000490337 / NM_172160.3; = p.L308P on NM_003471.3) | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as rs770591482, COSV100204463; called by muse, mutect2, varscan2
- KCND2 | c.13del p.V5Wfs*41 | Frame Shift Del (DEL) | VAF 26/84 reads (31%) | catalogued as COSV58583583, COSV58589056; called by mutect2, pindel, varscan2
- KCND2 | c.161C>T p.T54M | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58598129; called by muse, mutect2, varscan2
- KCND2 | c.1232G>A p.R411H | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.431); catalogued as rs779373502, COSV100476375, COSV100476653; called by muse, mutect2, varscan2
- KCNQ3 | c.1715dup p.T573Hfs*30 | Frame Shift Ins (INS) | VAF 27/95 reads (28%) | catalogued as rs796052684; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- KCNT2 | c.2002G>A p.A668T | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as COSV99654649; called by muse, mutect2, varscan2
- KDM2B | c.77del p.K26Rfs*81 | Frame Shift Del (DEL) | VAF 18/78 reads (23%) | catalogued as rs782541016; called by mutect2, pindel, varscan2
- KIAA1210 | c.3842C>T p.A1281V | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.134); catalogued as rs868072554, COSV101274260; called by muse, mutect2, varscan2
- KIF19 | c.1389C>T p.G463= | Splice Region (SNP) | VAF 10/114 reads (9%) | catalogued as COSV100739097; called by muse, mutect2
- KIF4A | c.1789C>T p.R597C | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs765737631, COSV65541234; called by muse, mutect2, varscan2
- KIF5A | c.2590C>T p.R864* | Nonsense Mutation (SNP) | VAF 19/47 reads (40%) | catalogued as CM166059, COSV99673142; called by muse, mutect2, varscan2
- KLF3 | c.654del p.L219* | Frame Shift Del (DEL) | VAF 9/23 reads (39%) | catalogued as rs1260051731; called by mutect2, pindel, varscan2
- KLHL36 | c.1499del p.G500Afs*142 | Frame Shift Del (DEL) | VAF 15/73 reads (21%) | catalogued as COSV50718067; called by mutect2, pindel, varscan2
- KMT2A | c.1220G>A p.R407Q | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV100629097; called by muse, mutect2, varscan2
- KMT2D | c.2630C>A p.P877H | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99983153; called by muse, mutect2, varscan2
- KSR1 | c.872del p.P291Hfs*36 (on ENST00000644974 / NM_001367810.1; = p.P154Hfs*36 on NM_014238.2) | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | catalogued as rs750491454; called by mutect2, varscan2
- L1CAM | c.1036C>T p.P346S | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV100649270; called by muse, mutect2, varscan2
- LAMA5 | c.5032C>A p.L1678M | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as COSV99440650; called by muse, mutect2, varscan2
- LARP1B | c.2257del p.M753Cfs*21 | Frame Shift Del (DEL) | VAF 17/65 reads (26%) | catalogued as rs1311334991; called by mutect2, pindel, varscan2
- LARS2 | c.950G>A p.S317N | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV99647925; called by muse, mutect2, varscan2
- LGI4 | c.511C>T p.Q171* | Nonsense Mutation (SNP) | VAF 7/32 reads (22%) | catalogued as COSV100032659; called by muse, mutect2, varscan2
- LHX2 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.168); catalogued as COSV101010065; called by muse, mutect2, varscan2
- LHX2 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.939); catalogued as COSV65317956; called by muse, mutect2, varscan2
- LIMD1 | c.215G>T p.R72M | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs762002629, COSV56267196, COSV56268030; called by muse, mutect2, varscan2
- LIN54 | c.1808G>A p.R603Q | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV61201460, COSV61203037; called by muse, mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 54/89 reads (61%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LMF2 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99327630; called by muse, mutect2, varscan2
- LPCAT4 | c.1172A>G p.D391G | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV100149065; called by muse, mutect2, varscan2
- LRBA | c.3548C>G p.T1183R | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV100841780; called by muse, mutect2, varscan2
- LRRC66 | c.1349G>A p.S450N | Missense Mutation (SNP) | VAF 59/148 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100603006; called by muse, mutect2, varscan2
- LRRC66 | c.884C>A p.P295H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as COSV100603007; called by muse, mutect2, varscan2
- LRRC8E | c.1558del p.Q520Rfs*3 | Frame Shift Del (DEL) | VAF 38/110 reads (35%) | catalogued as rs780986899, COSV60719674; called by mutect2, pindel, varscan2
- LTN1 | c.2500G>C p.A834P | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.361); catalogued as COSV100798034, COSV63735470; called by muse, mutect2, varscan2
- MAP2K2 | c.577C>T p.R193* | Nonsense Mutation (SNP) | VAF 19/51 reads (37%) | catalogued as COSV53563098; called by muse, mutect2, varscan2
- MAST2 | c.3512C>T p.T1171M | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.996); catalogued as rs777520826, COSV100788357; called by muse, mutect2, varscan2
- MBD5 | c.4252G>A p.E1418K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as rs577955398, COSV101290131; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- MCHR2 | c.623del p.F208Sfs*5 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | catalogued as rs759525627, COSV55999002; called by mutect2, varscan2
- MCM3AP | c.463A>G p.K155E | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV99387104; called by muse, mutect2, varscan2
- MCOLN2 | c.865T>C p.Y289H | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as rs369923860; called by muse, mutect2, varscan2
- MED14 | c.288C>A p.F96L | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as COSV100247524, COSV61356581; called by muse, mutect2, varscan2
- MED23 | c.1132C>T p.Q378* | Nonsense Mutation (SNP) | VAF 9/47 reads (19%) | catalogued as rs770689010, COSV100645115; called by muse, mutect2, varscan2
- MERTK | c.845-1G>A p.X282_splice | Splice Site (SNP) | VAF 50/115 reads (43%) | catalogued as COSV99774811; called by muse, mutect2, varscan2
- MICOS13 | c.150del p.A51Pfs*39 | Frame Shift Del (DEL) | VAF 5/20 reads (25%) | catalogued as rs751944867; called by mutect2, pindel, varscan2
- MINK1 | c.2989G>T p.V997L | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV99545068; called by muse, mutect2, varscan2
- MLXIP | c.2260A>G p.S754G | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV100038853; called by muse, mutect2, varscan2
- MMRN1 | c.2646del p.G883Afs*3 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as rs750319971; called by mutect2, pindel, varscan2
- MMS19 | c.2642A>G p.H881R | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs759325904, COSV100512921; called by muse, mutect2, varscan2
- MPO | c.1997G>A p.G666D | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs367639701; called by muse, mutect2
- MPP6 | c.917dup p.K307Efs*14 | Frame Shift Ins (INS) | VAF 17/46 reads (37%) | catalogued as rs757450051; ClinVar: not provided; called by mutect2, varscan2
- MRGPRX3 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.944); catalogued as rs747757094, COSV101283560; called by muse, mutect2, varscan2
- MRPL37 | c.881T>C p.L294P | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as COSV100289280; called by muse, mutect2, varscan2
- MRPL47 | c.475G>T p.G159C | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99372994; called by muse, mutect2, varscan2
- MTA2 | c.1163G>A p.C388Y | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.292); catalogued as rs1378012135, COSV99545399; called by muse, mutect2, varscan2
- MTMR4 | c.817A>G p.S273G | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100051140; called by muse, mutect2, varscan2
- MUC2 | c.608C>T p.S203L | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT tolerated (0.05); catalogued as rs766134241; called by muse, mutect2, varscan2
- MUC5B | c.8552C>T p.S2851L | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs201156729, COSV71590090; called by muse, mutect2, varscan2
- MUC5B | c.12323C>T p.S4108L | Missense Mutation (SNP) | VAF 25/208 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.133); catalogued as rs374548199; called by muse, mutect2, varscan2
- MXRA5 | c.6561G>A p.M2187I | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.193); catalogued as COSV99477595; called by muse, mutect2, varscan2
- MYH1 | c.1214C>A p.P405H | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99876231; called by muse, mutect2
- MYLK3 | c.884C>A p.P295H | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0.258); catalogued as COSV101189133; called by muse, mutect2, varscan2
- MYT1 | c.89G>A p.C30Y | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100114918; called by muse, mutect2
- NAAA | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.151); catalogued as rs772892418, COSV99715700; called by muse, mutect2, varscan2
- NALCN | c.4820G>A p.R1607Q | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs370886839, COSV99218045; called by muse, mutect2, varscan2
- NBEA | c.3362del p.N1121Mfs*9 | Frame Shift Del (DEL) | VAF 16/24 reads (67%) | catalogued as rs763376147; called by mutect2, varscan2
- NCKAP5 | c.1397A>C p.K466T | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.463); catalogued as COSV100492784; called by muse, mutect2, varscan2
- NCKIPSD | c.945G>T p.E315D | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as COSV99584030; called by muse, mutect2
- NEFM | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.789); catalogued as COSV55330931; called by muse, mutect2, varscan2
- NEO1 | c.1378C>T p.R460W | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99982291; called by muse, mutect2, varscan2
- NEURL4 | c.3889G>A p.G1297R | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as COSV100223059; called by muse, mutect2, varscan2
- NGLY1 | c.276del p.A93Lfs*12 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | catalogued as rs1217945461; called by mutect2, pindel
- NIPA2 | c.98del p.K33Rfs*12 | Frame Shift Del (DEL) | VAF 13/39 reads (33%) | catalogued as rs145147241; called by mutect2, varscan2
- NKAP | c.1102C>T p.R368* | Nonsense Mutation (SNP) | VAF 22/52 reads (42%) | catalogued as COSV100538316; called by muse, mutect2, varscan2
- NLRP3 | c.793G>A p.V265M | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.043); catalogued as COSV100276236, COSV60221100; called by muse, mutect2, varscan2
- NMBR | c.1148G>A p.S383N | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs763233633, COSV99237339; called by muse, mutect2, varscan2
- NPAT | c.3499A>G p.K1167E | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99586121; called by muse, mutect2, varscan2
- NPC1 | c.3367T>C p.S1123P | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV99340228; called by muse, mutect2
- NR1H4 | c.169T>C p.S57P (on ENST00000551379 / NM_001206993.2; = p.S47P on NM_005123.4) | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99500740; called by muse, mutect2, varscan2
- NTAN1 | c.831del p.K277Nfs*83 | Frame Shift Del (DEL) | VAF 19/77 reads (25%) | catalogued as COSV55073962; called by mutect2, pindel, varscan2
- NTAN1 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV55075064; called by muse, mutect2, varscan2
- NUDT12 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.148); catalogued as COSV100048228; called by muse, mutect2, varscan2
- NYAP2 | c.1226C>T p.A409V | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs367790714, COSV99797161; called by muse, mutect2, varscan2
- NYNRIN | c.1081C>T p.P361S | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV101230624; called by muse, mutect2, varscan2
- OAS2 | c.1277del p.N426Tfs*14 | Frame Shift Del (DEL) | VAF 18/51 reads (35%) | catalogued as rs781171419; called by mutect2, pindel, varscan2
- OBSCN | c.16285G>A p.A5429T | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.197); catalogued as COSV99480359; called by muse, mutect2, varscan2
- OBSCN | c.18787G>A p.A6263T | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs779560573, COSV52741099; called by muse, mutect2, varscan2
- OPN4 | c.1362del p.R455Dfs*16 | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | catalogued as rs1161778400; called by mutect2, pindel, varscan2
- OR10C1 | c.673A>G p.T225A (on ENST00000622521; = p.T223A on NM_013941.3) | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.096); catalogued as COSV101010847; called by muse, mutect2, varscan2
- OR2T10 | c.820T>C p.S274P | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV57896369; called by muse, mutect2, varscan2
- OR5K4 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100721360; called by muse, mutect2, varscan2
- OR8J1 | c.240A>C p.K80N | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as COSV100275061; called by muse, mutect2, varscan2
- OSBPL3 | c.289G>A p.G97S | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100514251; called by muse, mutect2, varscan2
- OSBPL7 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs201097417; called by muse, mutect2, varscan2
- OTUD4 | c.821G>A p.R274H (on ENST00000447906 / NM_001366057.1; = p.R209H on NM_001102653.1) | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs369308038; ClinVar: uncertain significance; called by muse, varscan2
- PALM2AKAP2 | c.1271G>A p.R424H (on ENST00000259318 / NM_001136562.3; = p.R655H on NM_007203.5) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1488977396, COSV99395379; called by muse, mutect2, varscan2
- PANX2 | c.659G>A p.S220N | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99348409; called by muse, mutect2, varscan2
- PAPLN | c.851G>A p.S284N (on ENST00000554301; = p.S257N on NM_173462.4) | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as COSV99389898; called by muse, mutect2, varscan2
- PAPPA2 | c.4340C>T p.T1447I | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.119); catalogued as COSV100868307; called by muse, mutect2, varscan2
- PAPSS1 | c.1625G>A p.G542D | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99492151; called by muse, mutect2, varscan2
- PAPSS1 | c.1358C>A p.P453H | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99492154; called by muse, mutect2, varscan2
- PARP14 | c.3499G>A p.V1167I | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs188219681, COSV101506294; called by muse, mutect2, varscan2
- PAX7 | c.260T>G p.L87R | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100946845; called by muse, mutect2, varscan2
- PBRM1 | c.4729G>A p.G1577S (on ENST00000296302 / NM_001366071.2; = p.G1470S on NM_018313.5) | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs200150658, COSV56263430, COSV56303941; called by muse, mutect2, varscan2
- PCDHA13 | c.1720G>A p.G574R | Missense Mutation (SNP) | VAF 70/128 reads (55%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.019); catalogued as COSV56502487; called by muse, mutect2, varscan2
- PCDHA6 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.226); catalogued as rs1554131172, COSV100972362; called by muse, mutect2, varscan2
- PCDHAC2 | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV99150511; called by muse, mutect2, varscan2
- PCDHGA10 | c.1942G>C p.V648L | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.654); catalogued as rs1229513014, COSV99540728; called by muse, mutect2, varscan2
- PCDHGB3 | c.1339G>A p.D447N | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99540721; called by muse, varscan2
- PCED1A | c.1269del p.C425Afs*11 | Frame Shift Del (DEL) | VAF 7/23 reads (30%) | catalogued as rs772305388; called by mutect2, pindel, varscan2
- PCGF3 | c.390C>G p.D130E | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1386368450, COSV100745292, COSV100745394; called by muse, mutect2, varscan2
- PCOLCE | c.1173del p.M392* | Frame Shift Del (DEL) | VAF 15/41 reads (37%) | catalogued as rs777844367; called by mutect2, pindel, varscan2
- PCSK1 | c.733G>A p.V245M | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV100227152; called by muse, mutect2
- PCSK6 | c.1000C>T p.R334W | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1409991747, COSV100083660; called by muse, mutect2, varscan2
- PDCD1 | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.848); catalogued as rs757334336, COSV57691727; called by muse, mutect2, varscan2
- PDZD2 | c.2078C>T p.P693L | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.236); catalogued as rs372245330, COSV99223634; called by muse, mutect2, varscan2
- PEAK1 | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs759331417, COSV56934716; called by muse, mutect2, varscan2
- PFKFB3 | c.755G>A p.C252Y | Missense Mutation (SNP) | VAF 15/83 reads (18%) | PolyPhen probably damaging (0.912); catalogued as COSV100432127; called by muse, mutect2, varscan2
- PHF3 | c.3408del p.V1137* | Frame Shift Del (DEL) | VAF 5/18 reads (28%) | catalogued as rs1163689977; called by mutect2, pindel, varscan2
- PHRF1 | c.1966C>T p.P656S (on ENST00000264555 / NM_001286581.2; = p.P655S on NM_020901.4) | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV99203451; called by muse, mutect2, varscan2
- PI4K2B | c.527G>A p.G176D | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99335522; called by muse, mutect2, varscan2
- PIP5K1A | c.1414C>T p.R472* (on ENST00000368888 / NM_001135638.2; = p.R459* on NM_003557.3) | Nonsense Mutation (SNP) | VAF 42/117 reads (36%) | catalogued as rs747336821, COSV100576654; called by muse, mutect2, varscan2
- PITX1 | c.212G>A p.G71D | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as rs775734536, COSV99530664; called by muse, mutect2, varscan2
- PKD1 | c.10262C>T p.P3421L (on ENST00000262304 / NM_001009944.3; = p.P3420L on NM_000296.4) | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs545053536, COSV99238362; called by muse, mutect2, varscan2
- PKD1L2 | c.2573C>T p.A858V | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as COSV100216716; called by muse, mutect2, varscan2
- PLEC | c.12145C>T p.R4049W (on ENST00000322810 / NM_201380.4; = p.R3939W on NM_000445.5) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.153); catalogued as rs782136681, COSV99055271; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEKHH3 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 49/160 reads (31%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs1484965984, COSV53189814; called by muse, mutect2, varscan2
- PLOD3 | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as rs201613747, COSV99778100; called by muse, mutect2, varscan2
- PLXNA2 | c.997G>A p.D333N | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs751507906, COSV100885583; called by muse, mutect2, varscan2
- PNPLA5 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.057); catalogued as rs552461775, COSV99336677; called by muse, mutect2, varscan2
- POLD3 | c.898del p.R300Gfs*5 | Frame Shift Del (DEL) | VAF 9/36 reads (25%) | catalogued as rs761423306, COSV55240660; called by mutect2, varscan2
- POLE | c.6072del p.V2025* | Frame Shift Del (DEL) | VAF 13/42 reads (31%) | catalogued as rs754630848; ClinVar: uncertain significance; called by mutect2, varscan2
- PPID | c.683del p.N228Tfs*23 | Frame Shift Del (DEL) | VAF 9/23 reads (39%) | catalogued as rs1386625884; called by mutect2, pindel, varscan2
- PPP1R9A | c.3284C>T p.A1095V | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as COSV99195610, COSV99196142; called by muse, mutect2, varscan2
- PPP3CA | c.542C>A p.A181D | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV100547794; called by muse, mutect2, varscan2
- PPRC1 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 4/88 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.211); catalogued as rs868562120; called by muse, mutect2
- PRAM1 | c.1783G>A p.D595N | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1219534236, COSV99725650; called by muse, mutect2, varscan2
- PRDM10 | c.3197C>T p.T1066M | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.907); catalogued as rs773270883, COSV58798992; called by muse, mutect2, varscan2
- PRICKLE2 | c.683T>C p.L228P (on ENST00000295902; = p.L172P on NM_198859.4) | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99897527; called by muse, mutect2, varscan2
- PRKDC | c.3799T>C p.Y1267H | Missense Mutation (SNP) | VAF 65/133 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100041159; called by muse, mutect2, varscan2
- PRPH2 | c.607C>T p.R203W | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV100028139; called by muse, mutect2, varscan2
- PRR14 | c.1570C>T p.R524W | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376888804; called by muse, mutect2, varscan2
- PRRG1 | c.401del p.P134Hfs*19 | Frame Shift Del (DEL) | VAF 26/62 reads (42%) | catalogued as rs781858060; called by mutect2, varscan2
- PRSS35 | c.967C>T p.R323W | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1474009747, COSV63800824; called by muse, mutect2
- PSMA8 | c.150del p.K50Nfs*12 | Frame Shift Del (DEL) | VAF 12/54 reads (22%) | catalogued as rs749240094; called by mutect2, varscan2
- PSME4 | c.2849T>C p.L950P | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV101122547; called by muse, mutect2, varscan2
- PTPN2 | c.622G>T p.D208Y | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV100518618; called by muse, mutect2, varscan2
- PTPRD | c.3507G>A p.L1169= | Splice Region (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100645315; called by muse, mutect2, varscan2
- PURG | c.107A>G p.H36R | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.012); catalogued as COSV53297676, COSV99989286; called by muse, mutect2
- PWWP2B | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV100535852; called by muse, mutect2
- PYGB | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as rs747769681, COSV99404779, COSV99405205; called by muse, mutect2, varscan2
- QRSL1 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV100945248; called by muse, mutect2, varscan2
- QSER1 | c.1907_1909del p.V636del (on ENST00000399302; = p.V765del on NM_001076786.3) | In Frame Del (DEL) | VAF 10/24 reads (42%) | catalogued as rs904916475; called by pindel, varscan2
- QTRT1 | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs748463873, COSV51553090, COSV99139065; called by muse, mutect2, varscan2
- QTRT1 | c.991C>T p.H331Y | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.257); catalogued as rs763866468, COSV99139067; called by muse, mutect2, varscan2
- RAB24 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.023); catalogued as COSV100293648, COSV57464019; called by muse, varscan2
- RASSF8 | c.122C>T p.T41I | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.907); catalogued as COSV99280862; called by muse, mutect2, varscan2
- RBM15B | c.1655G>A p.S552N | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.656); catalogued as rs782070372, COSV100082204; called by muse, mutect2, varscan2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 12/35 reads (34%) | catalogued as rs762006287; called by mutect2, varscan2
- RCC1 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1324614347, COSV100868145; called by muse, mutect2, varscan2
- RCOR2 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs772745604, COSV100036237; called by muse, mutect2, varscan2
- RECQL4 | c.1547C>T p.A516V | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs762113412, COSV99467128; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RET | c.674C>T p.T225M | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.266); catalogued as rs774670305, COSV60696594; called by muse, mutect2
- RFC3 | c.244del p.I82Lfs*25 | Frame Shift Del (DEL) | VAF 18/64 reads (28%) | catalogued as rs753959887; called by mutect2, varscan2
- RGS12 | c.3870del p.Q1292Rfs*49 | Frame Shift Del (DEL) | VAF 5/15 reads (33%) | catalogued as rs751982308; called by mutect2, varscan2
- RIN3 | c.1555G>A p.A519T | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.027); catalogued as rs1269708285, COSV99379460; called by muse, mutect2, varscan2
- RIPOR1 | c.659C>T p.A220V (on ENST00000379312 / NM_001193522.2; = p.A216V on NM_024519.4) | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV50225551; called by muse, mutect2, varscan2
- RNF141 | c.140A>G p.D47G | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); catalogued as COSV99792932; called by muse, mutect2
- RNF216 | c.2111G>A p.R704Q (on ENST00000425013 / NM_207116.3; = p.R761Q on NM_207111.4) | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1461715422, COSV101111326; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 30/40 reads (75%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPUSD2 | c.1430C>T p.T477I | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.081); catalogued as COSV100225215; called by muse, mutect2, varscan2
- RREB1 | c.3491G>A p.R1164H | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.226); catalogued as rs371044808; called by muse, mutect2, varscan2
- RTKN2 | c.1348del p.I450Lfs*67 | Frame Shift Del (DEL) | VAF 12/30 reads (40%) | catalogued as rs759252078; called by mutect2, varscan2
- RTL8C | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99924347; called by muse, mutect2, varscan2
- RTN1 | c.1155G>T p.E385D | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV99956002; called by muse, mutect2, varscan2
- RTTN | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); catalogued as rs1186610705; called by muse, mutect2, varscan2
- RYR2 | c.14482G>A p.G4828R | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1402571360, COSV63676464, COSV63717799; called by muse, mutect2, varscan2
- S100A1 | c.71G>T p.G24V | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99418020; called by muse, mutect2, varscan2
- SBK1 | c.359C>T p.T120I | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV100543569; called by muse, mutect2, varscan2
- SCLT1 | c.1620del p.A541Pfs*3 | Frame Shift Del (DEL) | VAF 16/52 reads (31%) | catalogued as rs760494753; called by mutect2, varscan2
- SCN2A | c.3500C>A p.P1167H | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99332205; called by muse, mutect2, varscan2
- SCN2B | c.496G>A p.V166I | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as rs140314864; called by muse, mutect2, varscan2
- SCN8A | c.3745C>G p.L1249V | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100633961, COSV61976402; called by muse, mutect2, varscan2
- SDC4 | c.104G>A p.G35D | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV101023492; called by muse, mutect2, varscan2
- SDCCAG8 | c.2009G>A p.S670N | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as COSV100285833; called by muse, mutect2, varscan2
- SDK2 | c.5383del p.V1795* | Frame Shift Del (DEL) | VAF 13/63 reads (21%) | catalogued as COSV66188538; called by mutect2, pindel, varscan2
- SEPTIN12 | c.880C>T p.H294Y | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99190801; called by muse, mutect2, varscan2
- SETD2 | c.4903T>C p.C1635R | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100339289; called by muse, mutect2, varscan2
- SETX | c.718G>T p.G240C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99810118; called by muse, mutect2, varscan2
- SFRP5 | c.852G>T p.W284C | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99823186; called by muse, mutect2, varscan2
- SH2B3 | c.1322T>C p.F441S | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100374333; called by muse, mutect2, varscan2
- SIN3A | c.2119C>T p.R707* | Nonsense Mutation (SNP) | VAF 18/52 reads (35%) | catalogued as COSV64581720; called by muse, mutect2, varscan2
- SIPA1L1 | c.964G>A p.V322I | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV100665674; called by muse, mutect2, varscan2
- SIX3 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV99578437; called by muse, mutect2
- SLC12A1 | c.2628del p.D877Mfs*46 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | catalogued as rs1419151341, COSV66797187; called by mutect2, varscan2
- SLC18A3 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV100340315; called by muse, varscan2
- SLC25A22 | c.506C>T p.T169M | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.305); catalogued as rs533726078, COSV100204067; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC25A45 | c.152C>A p.S51Y | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as COSV53684169, COSV99587347; called by muse, mutect2, varscan2
- SLC28A2 | c.1369-1G>T p.X457_splice | Splice Site (SNP) | VAF 38/84 reads (45%) | catalogued as COSV100754745; called by muse, mutect2, varscan2
- SLC2A4 | c.1040C>T p.A347V | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.166); catalogued as rs370389410, COSV99142861; called by muse, mutect2, varscan2
- SLC35G6 | c.647C>A p.P216H | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.924); catalogued as COSV100263479; called by muse, mutect2, varscan2
- SLC45A3 | c.1562C>T p.T521I | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.973); catalogued as COSV100901231; called by muse, mutect2
- SLC45A4 | c.745C>T p.H249Y (on ENST00000517878 / NM_001286646.2; = p.H198Y on NM_001080431.2) | Missense Mutation (SNP) | VAF 72/113 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99198659; called by muse, mutect2, varscan2
- SLC4A1 | c.2149G>A p.A717T | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as rs750490778, COSV99293409; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC4A2 | c.3227C>T p.A1076V | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.241); catalogued as COSV99879822; called by muse, mutect2, varscan2
- SLC4A3 | c.2581del p.A861Pfs*46 | Frame Shift Del (DEL) | VAF 10/27 reads (37%) | catalogued as COSV56095835; called by mutect2, pindel, varscan2
- SLC50A1 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); catalogued as rs758705595, COSV100310384; called by muse, mutect2, varscan2
- SLC50A1 | c.105G>A p.M35I | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.1); catalogued as COSV100310385; called by muse, mutect2, varscan2
- SLC6A7 | c.832del p.Q278Sfs*82 | Frame Shift Del (DEL) | VAF 25/64 reads (39%) | catalogued as COSV57939345; called by mutect2, pindel, varscan2
- SLFN5 | c.2345G>A p.R782Q | Missense Mutation (SNP) | VAF 54/94 reads (57%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1234377088, COSV55481324; called by muse, mutect2, varscan2
- SMARCA5 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.19); catalogued as COSV99303932; called by muse, mutect2, varscan2
- SMG8 | c.2909C>T p.P970L | Missense Mutation (SNP) | VAF 74/137 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99958900, COSV99959170; called by muse, mutect2, varscan2
- SNAPC4 | c.1651C>T p.Q551* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100047380; called by muse, mutect2
- SNRNP200 | c.2954G>A p.G985D | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100107717; called by muse, mutect2, varscan2
- SNRNP35 | c.548G>T p.R183M | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.338); catalogued as COSV100644575; called by muse, mutect2, varscan2
- SORL1 | c.4741del p.M1581Cfs*34 | Frame Shift Del (DEL) | VAF 18/60 reads (30%) | catalogued as rs1278336874; called by mutect2, varscan2
- SPAG9 | c.1645del p.R549Gfs*28 (on ENST00000262013 / NM_001130528.3; = p.R535Gfs*28 on NM_003971.6) | Frame Shift Del (DEL) | VAF 16/76 reads (21%) | catalogued as rs371303534; called by mutect2, varscan2
- SPEG | c.4223G>A p.S1408N | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.129); catalogued as COSV100404808; called by muse, varscan2
- SRSF12 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs370398820; called by muse, mutect2, varscan2
- SSTR2 | c.1004C>T p.T335I | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100192109; called by muse, mutect2, varscan2
- ST6GALNAC1 | c.569C>T p.T190I | Missense Mutation (SNP) | VAF 42/83 reads (51%) | PolyPhen benign (0.049); catalogued as COSV99336487; called by muse, mutect2, varscan2
- ST8SIA2 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 35/99 reads (35%) | PolyPhen benign (0.015); catalogued as rs370891354, COSV51572264; called by muse, mutect2, varscan2
- ST8SIA5 | c.703G>A p.V235M | Missense Mutation (SNP) | VAF 15/28 reads (54%) | PolyPhen probably damaging (0.966); catalogued as rs371266233; called by muse, mutect2, varscan2
- STAC2 | c.434_435del p.K145Sfs*9 | Frame Shift Del (DEL) | VAF 16/59 reads (27%) | catalogued as rs758389188; called by mutect2, pindel, varscan2
- STAG1 | c.295C>T p.Q99* | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | catalogued as COSV99365934; called by muse, mutect2, varscan2
- STAT2 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs200501174, COSV58476492; called by mutect2, varscan2
- STXBP2 | c.1096A>G p.S366G | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99657222; called by muse, mutect2, varscan2
- SUCO | c.867G>A p.M289I | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV99743080; called by muse, mutect2, varscan2
- SYK | c.98dup p.M34Hfs*3 | Frame Shift Ins (INS) | VAF 16/51 reads (31%) | catalogued as rs1182878074; called by mutect2, pindel, varscan2
- SYK | c.1561G>A p.A521T | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV101002510; called by muse, mutect2, varscan2
- SYNE2 | c.16687G>A p.V5563I | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs756909587, COSV100647956; called by muse, mutect2, varscan2
- SYT14 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 19/43 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs768568990, COSV100883743; called by muse, mutect2, varscan2
- SYTL1 | c.949C>T p.R317C (on ENST00000543823; = p.R305C on NM_032872.3) | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376143341; called by muse, mutect2, varscan2
- TAS2R4 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99924685; called by muse, mutect2
- TCERG1 | c.2870del p.K957Rfs*17 | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | catalogued as rs758822980; called by mutect2, varscan2
- TCF12 | c.546del p.V183Sfs*62 | Frame Shift Del (DEL) | VAF 29/73 reads (40%) | catalogued as rs1352708150; called by mutect2, pindel, varscan2
- TCHH | c.5114G>A p.R1705Q | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); catalogued as rs751590080, COSV64273593; called by muse, mutect2, varscan2
- TCOF1 | c.3492G>T p.Q1164H (on ENST00000377797 / NM_001135243.1; = p.Q1087H on NM_000356.4) | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as COSV100077700; called by muse, mutect2, varscan2
- TEC | c.1738C>T p.R580* | Nonsense Mutation (SNP) | VAF 13/38 reads (34%) | catalogued as rs779390935, COSV99972535; called by muse, mutect2, varscan2
- TENM1 | c.6772G>A p.A2258T | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.143); catalogued as rs377058853, COSV64431401; called by muse, mutect2, varscan2
- TFAM | c.441del p.E148Sfs*2 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | catalogued as rs544132101; called by mutect2, varscan2
- TFAP4 | c.548T>C p.M183T | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as rs1488357739, COSV99200071; called by muse, mutect2, varscan2
- TG | c.3862C>T p.Q1288* | Nonsense Mutation (SNP) | VAF 6/48 reads (13%) | catalogued as COSV99601559; called by muse, mutect2, varscan2
- TG | c.8229G>T p.E2743D | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV99601562; called by muse, mutect2, varscan2
- THBS2 | c.3157C>A p.Q1053K | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV100827942, COSV64680719; called by muse, mutect2, varscan2
- THSD1 | c.1708G>A p.A570T | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.43); PolyPhen benign (0.038); catalogued as COSV51626810; called by muse, mutect2, varscan2
- THUMPD1 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); catalogued as COSV101189717; called by muse, mutect2
- TIMD4 | c.152G>T p.S51I | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV50860121, COSV99192690; called by muse, mutect2, varscan2
- TM2D2 | c.482G>T p.G161V (on ENST00000456397 / NM_078473.3; = p.G118V on NM_031940.4) | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100205782; called by muse, mutect2, varscan2
- TM7SF3 | c.1279C>A p.L427I | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.39); catalogued as COSV100544860; called by muse, mutect2, varscan2
- TMA16 | c.45del p.V16Sfs*25 | Frame Shift Del (DEL) | VAF 13/19 reads (68%) | catalogued as rs570113265, COSV62187391; called by mutect2, varscan2
- TMA16 | c.200dup p.R68Efs*9 | Frame Shift Ins (INS) | VAF 11/38 reads (29%) | catalogued as rs768974165; called by mutect2, varscan2
- TMC7 | c.775A>G p.N259D | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV100432598; called by muse, mutect2, varscan2
- TMEM159 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs771794455, COSV51785337; called by muse, mutect2, varscan2
- TMEM184B | c.358+1G>A p.X120_splice | Splice Site (SNP) | VAF 14/40 reads (35%) | catalogued as COSV100725995; called by muse, mutect2, varscan2
- TMEM60 | c.231del p.A78Pfs*11 | Frame Shift Del (DEL) | VAF 50/74 reads (68%) | catalogued as rs749773249; called by mutect2, varscan2
- TMOD3 | c.282dup p.G95Rfs*22 | Frame Shift Ins (INS) | VAF 24/58 reads (41%) | catalogued as rs759399045; called by mutect2, varscan2
- TMPRSS11B | c.556G>A p.V186M | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.937); catalogued as COSV100219412; called by muse, mutect2, varscan2
- TMPRSS2 | c.404G>A p.G135D | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100151772; called by muse, mutect2, varscan2
- TMTC3 | c.2274dup p.C759Mfs*3 | Frame Shift Ins (INS) | VAF 8/24 reads (33%) | catalogued as rs1304750530; called by mutect2, varscan2
- TNS3 | c.1598C>T p.P533L | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs552081357, COSV60794516, COSV60800651; called by muse, mutect2, varscan2
- TOP3A | c.2495G>A p.G832D | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100329154; called by muse, mutect2, varscan2
- TPO | c.523C>T p.R175* | Nonsense Mutation (SNP) | VAF 14/29 reads (48%) | catalogued as rs763459820, CM076569, COSV61093527; called by muse, mutect2, varscan2
- TRAF6 | c.278G>A p.C93Y | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100777717; called by muse, mutect2, varscan2
- TRIM32 | c.1018C>T p.P340S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as COSV100528449; called by muse, mutect2, varscan2
- TRIO | c.4378G>A p.V1460M | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1031338685, COSV100710512; called by muse, mutect2
- TRIOBP | c.4436dup p.T1480Hfs*22 | Frame Shift Ins (INS) | VAF 20/48 reads (42%) | catalogued as rs756145453; called by mutect2, varscan2
- TRO | c.1186C>T p.Q396* | Nonsense Mutation (SNP) | VAF 14/36 reads (39%) | catalogued as rs1425451020, COSV99436682; called by muse, mutect2, varscan2
- TRPC5 | c.2459C>T p.S820F | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV53291803; called by muse, mutect2, varscan2
- TRPM6 | c.5381T>C p.I1794T | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as COSV100666568; called by muse, mutect2, varscan2
- TSHZ3 | c.2734G>A p.A912T | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as rs759742847, COSV53663538, COSV53671227; called by muse, mutect2, varscan2
- TSPAN32 | c.838C>T p.R280W | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs143225348; called by muse, mutect2, varscan2
- TTBK2 | c.2627del p.N876Ifs*10 | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | catalogued as rs1373884363; called by mutect2, pindel, varscan2
- TTC16 | c.817C>T p.R273W | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.636); catalogued as rs539719878, COSV100959902; called by muse, mutect2, varscan2
- TTI1 | c.2770del p.L924Wfs*37 | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | catalogued as rs760253164; called by mutect2, pindel, varscan2
- TTN | c.98906G>A p.R32969H (on ENST00000591111; = p.R25545H on NM_003319.4) | Missense Mutation (SNP) | VAF 16/44 reads (36%) | PolyPhen probably damaging (0.998); catalogued as rs550047610, COSV100618110; ClinVar: uncertain significance; called by muse, mutect2
- TTN | c.88129G>T p.G29377C (on ENST00000591111; = p.G21953C on NM_003319.4) | Missense Mutation (SNP) | VAF 17/48 reads (35%) | PolyPhen probably damaging (0.999); catalogued as COSV100618111; called by muse, mutect2, varscan2
- TTN | c.75875C>T p.T25292I (on ENST00000591111; = p.T17868I on NM_003319.4) | Missense Mutation (SNP) | VAF 18/45 reads (40%) | PolyPhen possibly damaging (0.773); catalogued as COSV100618112; called by muse, mutect2, varscan2
- TTN | c.60947C>T p.P20316L (on ENST00000591111; = p.P12892L on NM_003319.4) | Missense Mutation (SNP) | VAF 14/26 reads (54%) | PolyPhen probably damaging (0.999); catalogued as rs879192020, COSV100618113, COSV100630490; called by muse, mutect2, varscan2
- TTN | c.58769T>C p.L19590P (on ENST00000591111; = p.L12166P on NM_003319.4) | Missense Mutation (SNP) | VAF 11/36 reads (31%) | PolyPhen probably damaging (0.961); catalogued as COSV100618115; called by muse, mutect2, varscan2
- TUBB6 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100481118; called by muse, mutect2, varscan2
- UBE3B | c.2933G>A p.S978N | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100688849; called by muse, mutect2, varscan2
- UIMC1 | c.2145_2147del p.R717del | In Frame Del (DEL) | VAF 12/42 reads (29%) | catalogued as rs772457429; called by pindel, varscan2
- UNC13D | c.1385T>C p.L462P | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV99256958; called by muse, mutect2, varscan2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 22/35 reads (63%) | catalogued as rs767420916; called by mutect2, varscan2
- UPK2 | c.10del p.L4Cfs*9 | Frame Shift Del (DEL) | VAF 23/66 reads (35%) | catalogued as rs928096931; called by mutect2, pindel, varscan2
- UROC1 | c.920del p.K307Rfs*77 | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | catalogued as rs754361807; called by mutect2, varscan2
- USHBP1 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs202078592, COSV53104853; called by muse, mutect2, varscan2
- USP35 | c.1962del p.T655Pfs*23 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | catalogued as rs764735138; called by mutect2, varscan2
- UTP20 | c.392dup p.L131Ffs*27 | Frame Shift Ins (INS) | VAF 14/44 reads (32%) | catalogued as rs761528888; called by mutect2, varscan2
- UVRAG | c.709del p.S237Vfs*6 | Frame Shift Del (DEL) | VAF 14/34 reads (41%) | catalogued as rs762976381; called by mutect2, varscan2
- VASH1 | c.290G>T p.G97V | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as COSV99387981; called by muse, mutect2, varscan2
- VILL | c.762C>T p.Y254= | Splice Region (SNP) | VAF 9/28 reads (32%) | catalogued as rs1431969403, COSV99378972; called by muse, mutect2, varscan2
- VPS13A | c.2993T>C p.L998S | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100653013; called by muse, mutect2, varscan2
- VPS13D | c.6035T>C p.V2012A | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV99167249; called by muse, mutect2, varscan2
- VWF | c.7130dup p.H2378Afs*13 | Frame Shift Ins (INS) | VAF 6/14 reads (43%) | catalogued as rs267607359; ClinVar: not provided; called by mutect2, varscan2
- WBP2NL | c.35G>A p.R12H | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as rs1012053043, COSV99352199; called by muse, mutect2, varscan2
- WDR11 | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1481642523, COSV54785336; called by muse, mutect2, varscan2
- WDR6 | c.2421del p.R808Gfs*33 | Frame Shift Del (DEL) | VAF 16/45 reads (36%) | catalogued as rs750038548, COSV58247104; called by mutect2, pindel, varscan2
- WDR61 | c.77C>T p.T26I | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as COSV99144587; called by muse, mutect2, varscan2
- WDR72 | c.1510A>G p.K504E | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.63); PolyPhen benign (0.156); catalogued as COSV100854652; called by muse, mutect2, varscan2
- WDR81 | c.5042G>A p.G1681D (on ENST00000409644 / NM_001163809.2; = p.G630D on NM_152348.4) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs958625315, COSV100488996; called by muse, mutect2, varscan2
- WDR91 | c.1203G>T p.Q401H | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV100615719; called by muse, mutect2, varscan2
- WNK4 | c.1822del p.V608Cfs*53 | Frame Shift Del (DEL) | VAF 14/72 reads (19%) | catalogued as rs762079039; called by mutect2, pindel, varscan2
- XPOT | c.378del p.F126Lfs*6 | Frame Shift Del (DEL) | VAF 16/44 reads (36%) | catalogued as rs762052135; called by mutect2, varscan2
- XRCC5 | c.1478G>A p.C493Y | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101079664; called by muse, mutect2, varscan2
- XYLT2 | c.1687C>T p.R563C | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150417924; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- YIPF6 | c.582G>C p.W194C | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101006252; called by muse, mutect2, varscan2
- ZBTB17 | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.006); catalogued as COSV100999029; called by muse, mutect2, varscan2
- ZBTB40 | c.3491C>T p.T1164M | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs370617744; called by muse, mutect2, varscan2
- ZC3H14 | c.1559T>C p.V520A | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99193094; called by muse, mutect2, varscan2
- ZC3H14 | c.2098C>T p.H700Y | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.843); catalogued as COSV99193096; called by muse, mutect2, varscan2
- ZC3H18 | c.2037del p.R680Gfs*5 | Frame Shift Del (DEL) | VAF 10/23 reads (43%) | catalogued as rs751577786; called by mutect2, varscan2
- ZDHHC5 | c.1088C>T p.T363M | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.243); catalogued as rs372591056; called by muse, mutect2, varscan2
- ZFHX3 | c.3178G>A p.V1060I | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.684); catalogued as COSV99213378; called by muse, mutect2, varscan2
- ZFHX4 | c.10850A>G p.*3617Wext*2 | Nonstop Mutation (SNP) | VAF 3/12 reads (25%) | catalogued as COSV99264049; called by muse, mutect2
- ZFP37 | c.482del p.N161Ifs*24 | Frame Shift Del (DEL) | VAF 14/34 reads (41%) | catalogued as rs563751025; called by mutect2, varscan2
- ZIC1 | c.544A>T p.T182S | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.73); PolyPhen benign (0.01); catalogued as COSV99292069; called by muse, mutect2, varscan2
- ZMPSTE24 | c.1283C>T p.A428V | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV101032013; called by muse, mutect2, varscan2
- ZMYM3 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV58737172; called by muse, mutect2, varscan2
- ZNF324B | c.632C>T p.S211L | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs752106680, COSV100351694; called by muse, mutect2, varscan2
- ZNF490 | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0.187); catalogued as COSV100267405; called by muse, mutect2, varscan2
- ZNF560 | c.1142G>A p.C381Y | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100038722; called by muse, mutect2, varscan2
- ZNF579 | c.1666G>T p.G556W | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV100329281; called by muse, mutect2, varscan2
- ZNF608 | c.2845G>T p.G949C | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100101945; called by muse, mutect2, varscan2
- ZNF609 | c.2201del p.K734Rfs*12 | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | catalogued as rs760768847; called by mutect2, varscan2
- ZNF646 | c.1387C>T p.R463W | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372623067; called by muse, mutect2, varscan2
- ZNF648 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs760344463, COSV60569567; called by muse, mutect2, varscan2
- ZNF683 | c.433G>C p.A145P | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV62874014, COSV62875144; called by muse, mutect2, varscan2
- ZNF705A | c.850C>T p.H284Y | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100828327; called by muse, mutect2, varscan2
- ZNF786 | c.877del p.E293Rfs*88 | Frame Shift Del (DEL) | VAF 31/89 reads (35%) | catalogued as rs1341075761; called by mutect2, pindel, varscan2
- ABCA9 | c.496del p.M166* | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | called by mutect2, pindel, varscan2
- ALX4 | c.1016del p.P339Lfs*12 | Frame Shift Del (DEL) | VAF 32/94 reads (34%) | called by mutect2, pindel, varscan2
- AP3B1 | c.2769del p.K923Nfs*4 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | called by mutect2, varscan2
- ARHGAP24 | c.399dup p.G134Wfs*11 (on ENST00000395184 / NM_001025616.3; = p.G41Wfs*11 on NM_031305.3) | Frame Shift Ins (INS) | VAF 7/38 reads (18%) | called by mutect2, pindel, varscan2
- ARHGEF40 | c.4459del p.H1487Tfs*15 | Frame Shift Del (DEL) | VAF 17/51 reads (33%) | called by mutect2, pindel, varscan2
- ARID1A | c.4724dup p.P1576Tfs*27 | Frame Shift Ins (INS) | VAF 7/23 reads (30%) | called by mutect2, pindel, varscan2
- ARSD | c.1779del p.*594Efs*13 | Frame Shift Del (DEL) | VAF 32/108 reads (30%) | called by mutect2, pindel, varscan2
- ATXN1 | c.1953del p.F651Lfs*40 | Frame Shift Del (DEL) | VAF 25/76 reads (33%) | called by mutect2, pindel, varscan2
- BICC1 | c.1696del p.I566Sfs*5 | Frame Shift Del (DEL) | VAF 22/56 reads (39%) | called by mutect2, pindel, varscan2
- C2orf42 | c.1230del p.K410Nfs*38 | Frame Shift Del (DEL) | VAF 16/51 reads (31%) | called by mutect2, pindel, varscan2
- CAMTA2 | c.809del p.P270Qfs*6 | Frame Shift Del (DEL) | VAF 19/59 reads (32%) | called by mutect2, pindel, varscan2
- CAV1 | c.11del p.G4Afs*4 | Frame Shift Del (DEL) | VAF 14/76 reads (18%) | called by mutect2, pindel, varscan2
- CDH19 | c.153del p.F51Lfs*6 | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | called by mutect2, pindel, varscan2
- CELSR1 | c.5279_5290del p.E1760_L1764delinsV | In Frame Del (DEL) | VAF 25/84 reads (30%) | called by mutect2, pindel, varscan2
- CHD6 | c.1442dup p.N481Kfs*6 | Frame Shift Ins (INS) | VAF 13/36 reads (36%) | called by mutect2, pindel, varscan2
- CMTR1 | c.2141_2143del p.K714del | In Frame Del (DEL) | VAF 20/66 reads (30%) | called by pindel, varscan2
- CMTR2 | c.1763_1764del p.L588Pfs*2 | Frame Shift Del (DEL) | VAF 10/33 reads (30%) | called by pindel, varscan2
- CREB3L4 | c.910dup p.S304Ffs*22 | Frame Shift Ins (INS) | VAF 17/63 reads (27%) | called by mutect2, pindel, varscan2
- CREBBP | c.5366_5379del p.N1789Ifs*172 | Frame Shift Del (DEL) | VAF 23/66 reads (35%) | called by mutect2, pindel, varscan2
- CUL3 | c.429del p.L144* | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | called by mutect2, pindel, varscan2
- DLL1 | c.930dup p.S311Efs*20 | Frame Shift Ins (INS) | VAF 24/92 reads (26%) | called by mutect2, pindel, varscan2
- DMD | c.8751dup p.L2918Ifs*7 | Frame Shift Ins (INS) | VAF 10/44 reads (23%) | called by mutect2, pindel, varscan2
- DMXL1 | c.1229del p.L410Yfs*17 | Frame Shift Del (DEL) | VAF 13/46 reads (28%) | called by mutect2, pindel, varscan2
- DNAH1 | c.1413del p.K472Rfs*13 | Frame Shift Del (DEL) | VAF 24/88 reads (27%) | called by mutect2, pindel, varscan2
- DNAH11 | c.3918del p.F1306Lfs*11 | Frame Shift Del (DEL) | VAF 7/42 reads (17%) | called by mutect2, pindel, varscan2
- DNAH9 | c.12057del p.T4020Rfs*68 | Frame Shift Del (DEL) | VAF 8/25 reads (32%) | called by mutect2, pindel, varscan2
- DNAJA4 | c.61_63del p.E21del (on ENST00000343789; = p.E50del on NM_018602.3) | In Frame Del (DEL) | VAF 10/48 reads (21%) | called by pindel, varscan2
- EIF2A | c.818del p.N273Mfs*7 | Frame Shift Del (DEL) | VAF 15/64 reads (23%) | called by mutect2, pindel, varscan2
- EPC1 | c.18_23del p.F6_A8delinsL | In Frame Del (DEL) | VAF 15/45 reads (33%) | called by mutect2, pindel, varscan2
- EPHA7 | c.816del p.G273Efs*75 | Frame Shift Del (DEL) | VAF 20/59 reads (34%) | called by mutect2, pindel, varscan2
- ESRP1 | c.1064del p.G355Efs*33 | Frame Shift Del (DEL) | VAF 38/89 reads (43%) | called by mutect2, pindel, varscan2
- EZH2 | c.1169del p.G390Efs*29 (on ENST00000460911 / NM_001203247.2; = p.G395Efs*29 on NM_004456.5) | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | called by mutect2, pindel, varscan2
- FAM149A | c.1979del p.P660Rfs*2 (on ENST00000356371 / NM_001367768.2; = p.P369Rfs*2 on NM_015398.3 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 16/51 reads (31%) | called by mutect2, pindel, varscan2
- FCMR | c.338del p.G113Efs*8 | Frame Shift Del (DEL) | VAF 19/66 reads (29%) | called by mutect2, pindel, varscan2
- FLT3 | c.2955_2956del p.P986Afs*27 | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | called by pindel, varscan2
- FOXM1 | c.2008del p.E671Nfs*12 | Frame Shift Del (DEL) | VAF 7/23 reads (30%) | called by mutect2, pindel, varscan2
- FUBP3 | c.1184del p.P395Lfs*27 | Frame Shift Del (DEL) | VAF 15/44 reads (34%) | called by mutect2, pindel
- GAGE2E | c.244C>A p.P82T | Missense Mutation (SNP) | VAF 50/1506 reads (3%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.966); called by muse, mutect2
- GATB | c.1498del p.A500Hfs*9 | Frame Shift Del (DEL) | VAF 19/61 reads (31%) | called by mutect2, pindel, varscan2
- GMIP | c.2773del p.L925Cfs*104 | Frame Shift Del (DEL) | VAF 15/47 reads (32%) | called by mutect2, pindel, varscan2
- GPR15 | c.615dup p.V206Cfs*120 | Frame Shift Ins (INS) | VAF 30/79 reads (38%) | called by mutect2, pindel, varscan2
- GPR179 | c.3869del p.K1290Rfs*12 (on ENST00000621958; = p.K1289Rfs*12 on NM_001004334.4) | Frame Shift Del (DEL) | VAF 12/47 reads (26%) | called by mutect2, pindel, varscan2
- H4C5 | c.84_94del p.G29Afs*37 | Frame Shift Del (DEL) | VAF 13/66 reads (20%) | called by mutect2, pindel, varscan2
- HDLBP | c.506dup p.N169Kfs*23 | Frame Shift Ins (INS) | VAF 16/78 reads (21%) | called by mutect2, pindel, varscan2
- HORMAD1 | c.848del p.N283Tfs*12 | Frame Shift Del (DEL) | VAF 27/59 reads (46%) | called by mutect2, varscan2
- HOXD12 | c.589del p.A197Rfs*43 | Frame Shift Del (DEL) | VAF 14/52 reads (27%) | called by mutect2, pindel, varscan2
- IDE | c.1706dup p.L569Ffs*9 | Frame Shift Ins (INS) | VAF 14/42 reads (33%) | called by mutect2, varscan2
- IGSF10 | c.3060del p.R1021Gfs*41 | Frame Shift Del (DEL) | VAF 7/42 reads (17%) | called by mutect2, pindel, varscan2
- IL4R | c.1713dup p.T572Hfs*54 | Frame Shift Ins (INS) | VAF 15/53 reads (28%) | called by mutect2, pindel, varscan2
- ITSN2 | c.1547del p.K516Sfs*46 | Frame Shift Del (DEL) | VAF 22/66 reads (33%) | called by mutect2, pindel, varscan2
- JAG1 | c.618_620del p.F207del | In Frame Del (DEL) | VAF 8/35 reads (23%) | called by pindel, varscan2
- KCNB1 | c.2206del p.R736Gfs*9 | Frame Shift Del (DEL) | VAF 16/44 reads (36%) | called by mutect2, pindel, varscan2
- KCTD13 | c.854del p.G285Efs*48 | Frame Shift Del (DEL) | VAF 15/44 reads (34%) | called by mutect2, pindel, varscan2
- KDM6B | c.2025dup p.T676Hfs*8 | Frame Shift Ins (INS) | VAF 6/49 reads (12%) | called by mutect2, pindel, varscan2
- KDSR | c.493del p.V165Wfs*29 | Frame Shift Del (DEL) | VAF 19/35 reads (54%) | called by mutect2, pindel, varscan2
- KIF5B | c.1052del p.N351Ifs*60 | Frame Shift Del (DEL) | VAF 4/18 reads (22%) | called by mutect2, pindel, varscan2
- KMT2D | c.14494_14496del p.K4832del | In Frame Del (DEL) | VAF 23/49 reads (47%) | called by pindel, varscan2
- KMT2D | c.8851del p.H2951Tfs*53 | Frame Shift Del (DEL) | VAF 17/62 reads (27%) | called by mutect2, pindel, varscan2
- LPCAT3 | c.873+1del p.X291_splice | Splice Site (DEL) | VAF 11/38 reads (29%) | called by mutect2, pindel, varscan2
- LYST | c.3601del p.S1201Qfs*15 | Frame Shift Del (DEL) | VAF 14/48 reads (29%) | called by mutect2, pindel, varscan2
- MAP3K11 | c.2476del p.Q826Rfs*121 | Frame Shift Del (DEL) | VAF 15/78 reads (19%) | called by pindel, varscan2
- MAP3K14 | c.751del p.L251Cfs*40 | Frame Shift Del (DEL) | VAF 5/20 reads (25%) | called by mutect2, pindel, varscan2
- MCMDC2 | c.1105del p.R369Vfs*6 | Frame Shift Del (DEL) | VAF 39/73 reads (53%) | called by mutect2, pindel, varscan2
- MGAM | c.1658dup p.F554Ifs*28 | Frame Shift Ins (INS) | VAF 18/59 reads (31%) | called by mutect2, pindel, varscan2
- MS4A8 | c.326del p.F109Sfs*33 | Frame Shift Del (DEL) | VAF 27/81 reads (33%) | called by mutect2, pindel, varscan2
- MTA2 | c.385del p.Y129Tfs*33 | Frame Shift Del (DEL) | VAF 32/94 reads (34%) | called by mutect2, pindel, varscan2
- MVK | c.417del p.A141Rfs*18 | Frame Shift Del (DEL) | VAF 18/65 reads (28%) | called by mutect2, pindel, varscan2
- MYH3 | c.440dup p.R148Afs*13 | Frame Shift Ins (INS) | VAF 16/110 reads (15%) | called by mutect2, pindel, varscan2
- MYO15A | c.7302del p.R2435Gfs*35 | Frame Shift Del (DEL) | VAF 23/62 reads (37%) | called by mutect2, pindel, varscan2
- NCOA4 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NFATC4 | c.2163del p.Y722Tfs*122 | Frame Shift Del (DEL) | VAF 26/68 reads (38%) | called by mutect2, pindel, varscan2
- NR4A2 | c.588del p.L198Cfs*5 | Frame Shift Del (DEL) | VAF 22/75 reads (29%) | called by mutect2, pindel, varscan2
- OR8H2 | c.832del p.Y278Ifs*4 | Frame Shift Del (DEL) | VAF 11/36 reads (31%) | called by mutect2, pindel, varscan2
- PAK3 | c.774del p.K258Nfs*4 (on ENST00000262836 / NM_001324328.2; = p.K243Nfs*4 on NM_002578.5 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 11/34 reads (32%) | called by mutect2, pindel, varscan2
- PAN2 | c.3487_3488del p.F1163Pfs*9 (on ENST00000425394 / NM_001127460.3; = p.F1159Pfs*9 on NM_014871.5) | Frame Shift Del (DEL) | VAF 17/68 reads (25%) | called by mutect2, pindel, varscan2
- PATJ | c.4528del p.Q1510Rfs*37 | Frame Shift Del (DEL) | VAF 8/53 reads (15%) | called by mutect2, pindel, varscan2
- PCDHGC5 | c.1357del p.R453Afs*12 | Frame Shift Del (DEL) | VAF 13/67 reads (19%) | called by mutect2, pindel, varscan2
- PHACTR2 | c.677C>A p.S226* | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2, varscan2
- PHF14 | c.546del p.K182Nfs*19 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.202dup p.D68Gfs*38 | Frame Shift Ins (INS) | VAF 13/40 reads (33%) | called by mutect2, pindel, varscan2
- PLA2G15 | c.116del p.P39Qfs*39 | Frame Shift Del (DEL) | VAF 48/173 reads (28%) | called by mutect2, pindel, varscan2
- PPL | c.3517_3519del p.K1173del | In Frame Del (DEL) | VAF 12/33 reads (36%) | called by mutect2, pindel, varscan2
- PRAMEF8 | c.997C>A p.H333N | Missense Mutation (SNP) | VAF 54/229 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PTEN | c.628del p.T210Lfs*11 | Frame Shift Del (DEL) | VAF 6/29 reads (21%) | called by mutect2, pindel
- PTEN | c.838del p.I280Yfs*11 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | called by mutect2, pindel, varscan2
- PXDN | c.2592del p.N865Mfs*25 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | called by mutect2, pindel, varscan2
- RAI2 | c.1581del p.P528Qfs*5 | Frame Shift Del (DEL) | VAF 10/64 reads (16%) | called by mutect2, pindel, varscan2
- RCBTB2 | c.924del p.D308Efs*35 | Frame Shift Del (DEL) | VAF 29/88 reads (33%) | called by mutect2, pindel, varscan2
- RNF43 | c.1542del p.D516Ifs*11 | Frame Shift Del (DEL) | VAF 14/54 reads (26%) | called by mutect2, pindel, varscan2
- ROBO2 | c.904del p.M302Wfs*30 | Frame Shift Del (DEL) | VAF 17/40 reads (43%) | called by mutect2, pindel, varscan2
- RUVBL1 | c.697_698del p.E233Nfs*9 | Frame Shift Del (DEL) | VAF 12/49 reads (24%) | called by mutect2, pindel, varscan2
- SGK3 | c.749del p.F250Sfs*33 | Frame Shift Del (DEL) | VAF 37/87 reads (43%) | called by mutect2, pindel, varscan2
- SLAIN1 | c.930del p.T312Hfs*96 (on ENST00000466548; = p.T49Hfs*96 on NM_144595.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 14/38 reads (37%) | called by mutect2, pindel, varscan2
- SLC39A13 | c.172del p.A58Lfs*3 | Frame Shift Del (DEL) | VAF 29/67 reads (43%) | called by mutect2, pindel, varscan2
- SMCR8 | c.1847del p.P616Hfs*13 | Frame Shift Del (DEL) | VAF 13/41 reads (32%) | called by mutect2, pindel, varscan2
- SMPD2 | c.805del p.L269Sfs*7 | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | called by mutect2, pindel, varscan2
- SSBP2 | c.413del p.P138Hfs*2 | Frame Shift Del (DEL) | VAF 12/49 reads (24%) | called by mutect2, pindel, varscan2
- SYNE1 | c.10876del p.R3626Dfs*16 | Frame Shift Del (DEL) | VAF 24/84 reads (29%) | called by mutect2, pindel, varscan2
- TACR3 | c.41dup p.G15Wfs*24 | Frame Shift Ins (INS) | VAF 10/32 reads (31%) | called by mutect2, pindel, varscan2
- TAF15 | c.1027C>T p.R343C (on ENST00000605844 / NM_139215.3; = p.R340C on NM_003487.4) | Missense Mutation (SNP) | VAF 37/167 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TBCK | c.1del p.M1? | Frame Shift Del (DEL) | VAF 5/26 reads (19%) | called by mutect2, pindel
- TCERG1 | c.2947del p.I983Sfs*41 | Frame Shift Del (DEL) | VAF 12/28 reads (43%) | called by mutect2, varscan2
- TLR8 | c.2847del p.K949Nfs*19 (on ENST00000218032 / NM_138636.5; = p.K967Nfs*19 on NM_016610.4) | Frame Shift Del (DEL) | VAF 11/34 reads (32%) | called by mutect2, pindel, varscan2
- TMEM37 | c.445_447del p.L149del | In Frame Del (DEL) | VAF 18/76 reads (24%) | called by pindel, varscan2
268 further variants in this file (14 protein-altering or splice-affecting, 229 silent, 25 other) are not listed here.
